Somatic mutation profile of tumor specimen TCGA-B5-A1MW-01A (aliquot TCGA-B5-A1MW-01A-11D-A17D-09) from TCGA case TCGA-B5-A1MW, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: G3; Age at diagnosis: 55.3 years (20,183 days).
Specimen TCGA-B5-A1MW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b633da8e-b09c-42ad-99c2-073b75fa385c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B5-A1MW-10A (Blood Derived Normal), aliquot TCGA-B5-A1MW-10A-01D-A17D-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0225df58-9433-4786-8fe7-e49e123bc7a1

The open-access MAF lists 629 somatic variants for this specimen: 487 protein-altering or splice-affecting, 131 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 352, Silent 131, Frame Shift Ins 81, Splice Site 15, Nonsense Mutation 14, Frame Shift Del 13, Splice Region 7, Intron 3, RNA 3, 3'UTR 2, In Frame Del 2, 3'Flank 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AP1S1 | c.364dup p.D122Gfs*18 | Frame Shift Ins (INS) | VAF 21/39 reads (54%) | catalogued as rs767358930; ClinVar: likely pathogenic; called by mutect2, varscan2
- CTCF | c.610dup p.T204Nfs*26 | Frame Shift Ins (INS) | VAF 8/34 reads (24%) | catalogued as rs886041997; ClinVar: pathogenic; called by mutect2, varscan2
- CTNNB1 | c.121A>G p.T41A | Missense Mutation (SNP) | VAF 30/75 reads (40%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as rs121913412, COSV62687862, COSV62689580, COSV62714770; ClinVar: conflicting interpretations of pathogenicity / pathogenic /  other / likely pathogenic; called by muse, mutect2, varscan2
- FGFR2 | c.1144T>C p.C382R | Missense Mutation (SNP) | VAF 16/38 reads (42%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.536); catalogued as rs121913474, COSV60638681, COSV60642677; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- GATA2 | c.599dup p.S201* | Frame Shift Ins (INS) | VAF 26/95 reads (27%) | catalogued as rs768767517; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- KMT2D | c.303dup p.S102Efs*6 | Frame Shift Ins (INS) | VAF 16/49 reads (33%) | catalogued as rs797045661; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- MMUT | c.29dup p.L10Ffs*39 | Frame Shift Ins (INS) | VAF 18/40 reads (45%) | catalogued as rs1437477079; ClinVar: pathogenic; called by mutect2, varscan2
- OPLAH | c.2608dup p.H870Pfs*92 | Frame Shift Ins (INS) | VAF 30/82 reads (37%) | catalogued as rs781956288; ClinVar: pathogenic; called by mutect2, varscan2
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 20/35 reads (57%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PIK3R1 | c.1746-2A>G p.X582_splice (on ENST00000521381 / NM_181523.3; = p.X312_splice on NM_181504.4) | Splice Site (SNP) | VAF 32/71 reads (45%) | hotspot (GDC flag); catalogued as COSV57125460, COSV57131831, COSV57142185; called by muse, mutect2, varscan2
- ABCC6 | c.285A>T p.Q95H | Missense Mutation (SNP) | VAF 40/115 reads (35%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as COSV99229693; called by muse, mutect2, varscan2
- ABHD12 | c.973C>G p.L325V | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0.428); catalogued as rs538921932, COSV100194982; called by muse, mutect2, varscan2
- ACBD7 | c.115G>T p.G39* | Nonsense Mutation (SNP) | VAF 22/44 reads (50%) | catalogued as COSV100650450; called by muse, mutect2, varscan2
- ACSM2A | c.895A>G p.T299A (on ENST00000219054; = p.T220A on NM_001308169.2) | Missense Mutation (SNP) | VAF 48/92 reads (52%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV54588718; called by muse, mutect2, varscan2
- ACSM2B | c.68T>C p.L23P | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.736); catalogued as COSV100313185; called by muse, mutect2, varscan2
- ACVR1C | c.1370T>C p.M457T | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.729); catalogued as rs1470044668, COSV99695088; called by muse, mutect2, varscan2
- ADAM32 | c.803T>C p.L268P | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.445); catalogued as COSV65950121; called by muse, mutect2, varscan2
- ADAMTS3 | c.2954G>T p.G985V | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99712170; called by muse, mutect2, varscan2
- ADAMTS6 | c.1075T>A p.Y359N | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT tolerated (0.15); PolyPhen benign (0.445); catalogued as COSV101125473; called by muse, varscan2
- ADARB1 | c.1892A>G p.Q631R (on ENST00000360697 / NM_001346687.2; = p.Q591R on NM_001112.4) | Missense Mutation (SNP) | VAF 25/45 reads (56%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.893); catalogued as COSV100654134; called by muse, mutect2, varscan2
- ADCY1 | c.3264dup p.V1089Rfs*97 | Frame Shift Ins (INS) | VAF 20/66 reads (30%) | catalogued as rs779691962; called by mutect2, pindel, varscan2
- ADNP2 | c.971dup p.A325Cfs*59 | Frame Shift Ins (INS) | VAF 36/101 reads (36%) | catalogued as rs772825390; called by mutect2, varscan2
- AGFG1 | c.1409T>C p.M470T | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.165); catalogued as COSV100029211; called by muse, mutect2
- AHCTF1 | c.2587G>T p.D863Y (on ENST00000366508; = p.D837Y on NM_015446.5) | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV100404485; called by muse, mutect2, varscan2
- AHNAK | c.9373G>A p.V3125M | Missense Mutation (SNP) | VAF 69/150 reads (46%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.967); catalogued as rs79187953; called by muse, mutect2, varscan2
- AHNAK2 | c.2798G>A p.G933D | Missense Mutation (SNP) | VAF 65/148 reads (44%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.993); catalogued as COSV100319067; called by muse, mutect2, varscan2
- ALPK1 | c.3035-1G>T p.X1012_splice | Splice Site (SNP) | VAF 24/51 reads (47%) | catalogued as COSV99455246; called by muse, mutect2, varscan2
- AMBN | c.956A>G p.E319G | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs376165259; called by muse, mutect2, varscan2
- ANGPT2 | c.142C>A p.P48T | Missense Mutation (SNP) | VAF 45/156 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100291233; called by muse, mutect2, varscan2
- ANK1 | c.1089A>C p.K363N | Missense Mutation (SNP) | VAF 26/118 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as COSV99226983; called by muse, mutect2, varscan2
- ANKEF1 | c.2099A>G p.N700S | Missense Mutation (SNP) | VAF 29/83 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101001079; called by muse, mutect2, varscan2
- ANKRD27 | c.1291T>C p.C431R | Missense Mutation (SNP) | VAF 43/104 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100043190; called by muse, mutect2, varscan2
- AP1G1 | c.740T>C p.V247A | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV100250135; called by muse, mutect2, varscan2
- AP1M1 | c.163dup p.V55Gfs*32 | Frame Shift Ins (INS) | VAF 28/102 reads (27%) | catalogued as rs753324780; called by mutect2, varscan2
- ARFGEF3 | c.1280T>C p.V427A | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.427); catalogued as COSV99294793; called by muse, mutect2, varscan2
- ARHGAP6 | c.1880T>C p.L627S | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV57302003; called by muse, mutect2, varscan2
- ARHGEF9 | c.1496G>A p.R499H | Missense Mutation (SNP) | VAF 45/106 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.902); catalogued as rs781858542, COSV53634623; called by muse, mutect2, varscan2
- ARID2 | c.4409C>T p.S1470L | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT tolerated, low confidence (0.28); PolyPhen probably damaging (0.977); catalogued as COSV100537100, COSV57607789, COSV57617042; called by muse, mutect2, varscan2
- ARID2 | c.4540A>G p.T1514A | Missense Mutation (SNP) | VAF 19/31 reads (61%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.039); catalogued as COSV100537103; called by muse, mutect2, varscan2
- ASCC3 | c.5996T>C p.L1999P | Missense Mutation (SNP) | VAF 38/95 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1332043274, COSV100976951; called by muse, mutect2
- ASPM | c.6440A>G p.Q2147R | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99661184; called by muse, mutect2, varscan2
- ATAD2B | c.883T>C p.Y295H | Missense Mutation (SNP) | VAF 52/99 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99478525; called by muse, mutect2, varscan2
- ATP10B | c.452A>G p.N151S | Missense Mutation (SNP) | VAF 29/74 reads (39%) | SIFT tolerated (0.75); PolyPhen benign (0.001); catalogued as COSV100469778; called by muse, mutect2, varscan2
- ATP6V1A | c.1069G>A p.A357T | Missense Mutation (SNP) | VAF 30/68 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99850429; called by muse, mutect2, varscan2
- B4GALNT2 | c.367A>G p.R123G | Missense Mutation (SNP) | VAF 40/88 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.15); catalogued as COSV100302794; called by muse, mutect2, varscan2
- BARHL2 | c.577A>G p.T193A | Missense Mutation (SNP) | VAF 52/116 reads (45%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV100966113; called by muse, mutect2, varscan2
- BBS12 | c.1024A>G p.N342D | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT tolerated (0.15); PolyPhen benign (0.039); catalogued as rs751182253, COSV100045116; called by muse, mutect2, varscan2
- BICDL1 | c.475C>T p.R159* | Nonsense Mutation (SNP) | VAF 41/73 reads (56%) | catalogued as rs376989285, COSV101287357; called by muse, mutect2, varscan2
- BIRC6 | c.14395C>T p.R4799C | Missense Mutation (SNP) | VAF 30/77 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs759980874, COSV101429007; called by muse, mutect2, varscan2
- BMP1 | c.2042T>C p.M681T | Missense Mutation (SNP) | VAF 8/160 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.876); catalogued as rs1475121734, COSV100110176; called by muse, mutect2
- BMP5 | c.836G>A p.R279H | Missense Mutation (SNP) | VAF 49/91 reads (54%) | SIFT tolerated (0.81); PolyPhen probably damaging (0.922); catalogued as rs372083649; called by muse, mutect2, varscan2
- BMPER | c.230T>A p.V77E | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as COSV99780640; called by muse, mutect2, varscan2
- BSCL2 | c.397T>G p.Y133D | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV99628535; called by muse, mutect2, varscan2
- BTBD3 | c.1039G>A p.D347N | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.59); PolyPhen benign (0.028); catalogued as COSV99655979; called by muse, mutect2, varscan2
- BUD13 | c.528_530del p.P177del | In Frame Del (DEL) | VAF 18/36 reads (50%) | catalogued as rs1473168649; called by pindel, varscan2
- CA5B | c.369C>A p.N123K | Missense Mutation (SNP) | VAF 47/95 reads (49%) | SIFT tolerated (0.96); PolyPhen benign (0.026); catalogued as COSV100590833; called by muse, mutect2, varscan2
- CACNA1B | c.4685T>C p.I1562T | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as COSV99500058; called by muse, mutect2, varscan2
- CAPN12 | c.1831G>A p.A611T | Missense Mutation (SNP) | VAF 26/48 reads (54%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV53150820; called by muse, mutect2, varscan2
- CASP1 | c.888A>C p.K296N (on ENST00000436863 / NM_033292.4; = p.K275N on NM_001223.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT tolerated (0.24); PolyPhen benign (0.011); catalogued as rs3737531, COSV100782859; called by muse, mutect2, varscan2
- CASR | c.1995G>T p.W665C (on ENST00000490131; = p.W742C on NM_000388.4) | Missense Mutation (SNP) | VAF 18/33 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99949509; called by muse, mutect2, varscan2
- CCL13 | c.89T>C p.V30A | Missense Mutation (SNP) | VAF 26/55 reads (47%) | SIFT tolerated (0.59); PolyPhen benign (0.006); catalogued as COSV99861852; called by muse, mutect2, varscan2
- CCNB3 | c.1768G>T p.E590* | Nonsense Mutation (SNP) | VAF 15/34 reads (44%) | catalogued as COSV52079533, COSV99329954; called by muse, mutect2, varscan2
- CD207 | c.578A>C p.Q193P | Missense Mutation (SNP) | VAF 10/130 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.536); catalogued as COSV101338596; called by muse, mutect2
- CD2AP | c.420+2T>C p.X140_splice | Splice Site (SNP) | VAF 5/77 reads (6%) | catalogued as COSV100830656; called by muse, mutect2
- CD81 | c.629T>C p.I210T | Missense Mutation (SNP) | VAF 29/74 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.197); catalogued as COSV99719215, COSV99719283; called by muse, mutect2, varscan2
- CDC42BPG | c.1384+2T>C p.X462_splice | Splice Site (SNP) | VAF 13/27 reads (48%) | catalogued as rs1304223349, COSV100712168; called by muse, mutect2, varscan2
- CDH1 | c.1988A>T p.Y663F | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV99932730; called by muse, mutect2, varscan2
- CDKN2C | c.80A>C p.N27T | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT tolerated (0.53); PolyPhen benign (0.011); catalogued as COSV99396076; called by muse, mutect2, varscan2
- CDRT1 | c.1882G>T p.V628F | Missense Mutation (SNP) | VAF 63/144 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV100600002; called by muse, mutect2, varscan2
- CELSR1 | c.7781C>T p.P2594L | Missense Mutation (SNP) | VAF 43/92 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99420194; called by muse, mutect2, varscan2
- CEP170B | c.3977A>G p.E1326G (on ENST00000453495; = p.E1255G on NM_015005.3) | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.403); catalogued as COSV99229957; called by muse, mutect2, varscan2
- CEP76 | c.1202C>A p.T401N | Missense Mutation (SNP) | VAF 33/76 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100043017; called by muse, mutect2, varscan2
- CFAP157 | c.1495C>T p.R499C | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.533); catalogued as rs752171285, COSV58852665, COSV58853238; called by muse, mutect2, varscan2
- CFAP70 | c.16T>C p.S6P | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.027); catalogued as COSV100161096; called by muse, mutect2, varscan2
- CFH | c.617T>C p.V206A | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.827); catalogued as COSV100661668; called by muse, mutect2, varscan2
- CHMP7 | c.1334A>G p.Q445R | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT tolerated (0.54); PolyPhen benign (0.043); catalogued as COSV100500785; called by muse, mutect2, varscan2
- COBLL1 | c.2420T>C p.M807T (on ENST00000392717; = p.M769T on NM_014900.5) | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1419666245, COSV99528744; called by muse, mutect2, varscan2
- COL12A1 | c.2369T>C p.V790A | Missense Mutation (SNP) | VAF 38/101 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.44); catalogued as COSV100486617; called by muse, mutect2, varscan2
- COL18A1 | c.5009G>A p.R1670H (on ENST00000359759 / NM_130444.3; = p.R1435H on NM_030582.4) | Missense Mutation (SNP) | VAF 28/62 reads (45%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.967); catalogued as rs757116735, COSV60589336; called by muse, mutect2
- COLEC11 | c.470T>C p.V157A | Missense Mutation (SNP) | VAF 9/102 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.778); catalogued as COSV99363718; called by muse, mutect2
- COPS2 | c.512T>A p.I171N | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV54645624; called by muse, mutect2, varscan2
- CPNE5 | c.418A>C p.S140R | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV99783359; called by muse, mutect2, varscan2
- CSMD3 | c.484A>G p.S162G | Missense Mutation (SNP) | VAF 29/85 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.146); catalogued as COSV52216988; called by muse, mutect2, varscan2
- CTSW | c.793A>G p.N265D | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.557); catalogued as rs1461768633, COSV100327569; called by muse, mutect2, varscan2
- CXXC1 | c.1223T>C p.L408P | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99497339; called by muse, mutect2, varscan2
- CYB5R1 | c.821T>C p.L274P | Missense Mutation (SNP) | VAF 42/104 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100579680; called by muse, mutect2, varscan2
- CYP21A2 | c.1010A>G p.Y337C | Missense Mutation (SNP) | VAF 61/130 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100926038; called by muse, mutect2, varscan2
- CYSLTR2 | c.752T>C p.I251T | Missense Mutation (SNP) | VAF 39/79 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.724); catalogued as COSV99935424; called by muse, mutect2, varscan2
- DAB1 | c.1223T>C p.L408S (on ENST00000371231; = p.L375S on NM_021080.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 5/101 reads (5%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.864); catalogued as COSV100976694; called by muse, mutect2
- DACT1 | c.1724A>G p.N575S | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as COSV100242151; called by muse, mutect2, varscan2
- DCAF8 | c.1601T>C p.L534S | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV100470891; called by muse, mutect2, varscan2
- DCTN1 | c.992G>A p.R331Q | Missense Mutation (SNP) | VAF 28/52 reads (54%) | SIFT tolerated (0.09); PolyPhen benign (0.029); catalogued as rs773056643, COSV100721101, COSV62620765; called by muse, mutect2, varscan2
- DCTN3 | c.32A>C p.Q11P | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.648); catalogued as COSV99427075; called by muse, mutect2, varscan2
- DGLUCY | c.1222G>A p.G408R | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT tolerated (0.17); PolyPhen benign (0.018); catalogued as COSV99824767; called by muse, mutect2, varscan2
- DHX34 | c.314G>A p.R105H | Missense Mutation (SNP) | VAF 46/94 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as rs773853473, COSV100169935; called by muse, mutect2, varscan2
- DHX34 | c.2279dup p.G761Rfs*4 | Frame Shift Ins (INS) | VAF 26/57 reads (46%) | catalogued as rs763046010; called by mutect2, varscan2
- DHX9 | c.2545A>G p.T849A | Missense Mutation (SNP) | VAF 55/124 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV100841537; called by muse, mutect2, varscan2
- DIDO1 | c.6661G>A p.A2221T | Missense Mutation (SNP) | VAF 43/97 reads (44%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0.001); catalogued as rs201786226, COSV99827256; called by muse, mutect2, varscan2
- DMD | c.10958G>A p.S3653N | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.091); catalogued as COSV100629525; called by muse, mutect2, varscan2
- DNAH2 | c.6856T>C p.S2286P | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.265); catalogued as COSV101209618; called by muse, mutect2, varscan2
- DNAH7 | c.6508A>G p.T2170A | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100417787; called by muse, mutect2, varscan2
- DNHD1 | c.899T>C p.V300A | Missense Mutation (SNP) | VAF 32/79 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.093); catalogued as COSV99601038; called by muse, mutect2, varscan2
- DNMT3B | c.839T>C p.L280P | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99144561; called by muse, mutect2
- DOCK10 | c.506C>T p.S169L | Missense Mutation (SNP) | VAF 22/43 reads (51%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.99); catalogued as COSV99291825; called by muse, mutect2, varscan2
- DOK4 | c.821T>C p.I274T | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV99538481; called by muse, mutect2, varscan2
- DPH3 | c.47A>G p.D16G | Missense Mutation (SNP) | VAF 45/79 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV99550951; called by muse, mutect2, varscan2
- DPP6 | c.1322A>C p.K441T (on ENST00000377770 / NM_001364500.2; = p.K379T on NM_001936.5) | Missense Mutation (SNP) | VAF 32/101 reads (32%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.849); catalogued as COSV100128353; called by muse, mutect2, varscan2
- DYNC1I2 | c.1477T>C p.F493L | Missense Mutation (SNP) | VAF 28/56 reads (50%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as COSV99784360; called by muse, mutect2, varscan2
- ECPAS | c.2918T>C p.V973A | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.341); catalogued as COSV99399385; called by muse, mutect2, varscan2
- EIF2AK2 | c.519A>G p.K173= | Splice Region (SNP) | VAF 16/35 reads (46%) | catalogued as COSV99241054; called by muse, mutect2, varscan2
- ELFN2 | c.73T>C p.W25R | Missense Mutation (SNP) | VAF 31/60 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101297655; called by muse, mutect2, varscan2
- ENTPD5 | c.1241T>C p.L414S | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV99474211; called by muse, mutect2, varscan2
- EPB41L4A | c.107C>T p.T36M | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); catalogued as rs187394282, COSV99814183; called by muse, mutect2, varscan2
- EPB41L4B | c.2223G>T p.K741N | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.991); catalogued as COSV100775854; called by muse, mutect2, varscan2
- EPHB6 | c.165+1dup | Frame Shift Ins (INS) | VAF 28/66 reads (42%) | catalogued as rs771807343; called by mutect2, varscan2
- ERICH1 | c.824T>A p.V275E | Missense Mutation (SNP) | VAF 40/188 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as rs762087184, COSV100033111; called by muse, mutect2, varscan2
- ERICH1 | c.653C>T p.P218L | Missense Mutation (SNP) | VAF 31/165 reads (19%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs369345572, COSV100032339; called by muse, mutect2, varscan2
- ERICH3 | c.155A>G p.Y52C | Missense Mutation (SNP) | VAF 25/51 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100445910; called by muse, mutect2, varscan2
- ERMP1 | c.2155A>T p.I719F | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT tolerated (0.28); PolyPhen benign (0.145); catalogued as COSV99284805; called by muse, mutect2, varscan2
- ESF1 | c.512dup p.N171Kfs*24 | Frame Shift Ins (INS) | VAF 36/66 reads (55%) | catalogued as rs745713173; called by mutect2, varscan2
- F8 | c.6922T>C p.S2308P | Missense Mutation (SNP) | VAF 49/97 reads (51%) | SIFT tolerated (0.21); PolyPhen benign (0.296); catalogued as COSV100371854; called by muse, mutect2, varscan2
- FAM13A | c.2456A>G p.H819R | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99984751; called by muse, mutect2
- FAM155B | c.494dup p.L166Sfs*5 | Frame Shift Ins (INS) | VAF 24/45 reads (53%) | catalogued as rs769524017; called by mutect2, varscan2
- FAM167A | c.234del p.Q79Rfs*7 | Frame Shift Del (DEL) | VAF 75/138 reads (54%) | catalogued as COSV52702654, COSV52703303; called by mutect2, pindel, varscan2
- FANCD2 | c.3689C>T p.T1230I | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as rs773540135, COSV99812582; called by muse, mutect2, varscan2
- FANCI | c.2818G>T p.E940* (on ENST00000310775 / NM_001376911.1; = p.E880* on NM_018193.3) | Nonsense Mutation (SNP) | VAF 20/39 reads (51%) | catalogued as COSV100168622; called by muse, mutect2, varscan2
- FASN | c.260A>G p.Y87C | Missense Mutation (SNP) | VAF 50/116 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100148369; called by muse, mutect2, varscan2
- FAXC | c.833A>G p.K278R | Missense Mutation (SNP) | VAF 4/53 reads (8%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.647); catalogued as COSV101067272; called by muse, mutect2
- FBXL7 | c.347G>A p.R116Q | Missense Mutation (SNP) | VAF 26/48 reads (54%) | SIFT tolerated (0.47); PolyPhen benign (0.037); catalogued as rs375773578, COSV61654337; called by muse, mutect2, varscan2
- FBXO43 | c.1459G>A p.G487S | Missense Mutation (SNP) | VAF 98/135 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101413925; called by muse, mutect2, varscan2
- FCAMR | c.1455T>C p.R485= (on ENST00000324852 / NM_001170631.2; = p.V218A on NM_032029.4) | Splice Region (SNP) | VAF 21/47 reads (45%) | catalogued as COSV61368739; called by muse, mutect2, varscan2
- FEZF2 | c.617C>A p.A206D | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT tolerated (0.15); PolyPhen benign (0.127); catalogued as COSV99335014; called by muse, mutect2, varscan2
- FGF10 | c.617T>C p.V206A | Missense Mutation (SNP) | VAF 67/162 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.835); catalogued as COSV52933523, COSV99241025; called by muse, mutect2, varscan2
- FGR | c.911T>C p.L304P | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100925917; called by muse, mutect2, varscan2
- FILIP1L | c.3334A>G p.T1112A (on ENST00000354552 / NM_182909.3; = p.T872A on NM_014890.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 147/340 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.052); catalogued as COSV100497405; called by muse, mutect2, varscan2
- FKBP9 | c.384dup p.N129Qfs*7 | Frame Shift Ins (INS) | VAF 66/162 reads (41%) | catalogued as rs752076602; called by mutect2, varscan2
- FLNB | c.7142C>T p.A2381V | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT tolerated (0.39); PolyPhen benign (0.009); catalogued as rs752183022, COSV99915079; called by muse, mutect2, varscan2
- FLRT1 | c.193A>G p.I65V | Missense Mutation (SNP) | VAF 5/76 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs911442119, COSV99736301; called by muse, mutect2
- FOXA2 | c.345dup p.Q116Afs*123 (on ENST00000377115 / NM_153675.3; = p.Q122Afs*123 on NM_021784.5) | Frame Shift Ins (INS) | VAF 9/24 reads (38%) | catalogued as rs763459424; called by mutect2, pindel, varscan2
- FRYL | c.3406T>C p.W1136R | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV99978292; called by muse, mutect2, varscan2
- FXR1 | c.1575T>A p.D525E | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.952); catalogued as rs775129645, COSV99976695; called by muse, mutect2, varscan2
- FYB2 | c.1851dup p.E618Rfs*6 | Frame Shift Ins (INS) | VAF 12/38 reads (32%) | catalogued as rs751048223; called by mutect2, varscan2
- FYN | c.1445G>A p.G482D | Missense Mutation (SNP) | VAF 54/117 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99992597; called by muse, mutect2, varscan2
- GART | c.2420del p.K807Rfs*7 | Frame Shift Del (DEL) | VAF 18/37 reads (49%) | catalogued as rs758551787; called by mutect2, varscan2
- GATA2 | c.1146T>C p.V382= | Splice Region (SNP) | VAF 12/17 reads (71%) | catalogued as COSV100351576; called by muse, mutect2, varscan2
- GGCT | c.427A>T p.I143F | Missense Mutation (SNP) | VAF 43/81 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV99139219; called by muse, mutect2, varscan2
- GLB1L3 | c.281T>C p.I94T | Missense Mutation (SNP) | VAF 34/72 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as COSV101111125; called by muse, mutect2, varscan2
- GLYR1 | c.1140dup p.R381Afs*15 | Frame Shift Ins (INS) | VAF 14/44 reads (32%) | catalogued as rs749150409; called by mutect2, varscan2
- GNAZ | c.612dup p.Q205Afs*35 | Frame Shift Ins (INS) | VAF 34/80 reads (43%) | catalogued as rs752075537; called by mutect2, varscan2
- GPR142 | c.347A>G p.E116G | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0); catalogued as COSV100171033; called by muse, mutect2, varscan2
- GPR32 | c.155C>T p.A52V | Missense Mutation (SNP) | VAF 96/203 reads (47%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs893372939, COSV99567180; called by muse, mutect2, varscan2
- GPX4 | c.100G>A p.D34N | Missense Mutation (SNP) | VAF 37/82 reads (45%) | SIFT tolerated (0.3); PolyPhen benign (0.01); catalogued as rs1456925736, COSV100685052; called by muse, mutect2, varscan2
- GRIA2 | c.809T>C p.V270A | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV99646076; called by muse, mutect2, varscan2
- GTF3C2 | c.2534A>G p.N845S | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99273317; called by muse, mutect2, varscan2
- HCFC1 | c.5234C>T p.A1745V | Missense Mutation (SNP) | VAF 69/152 reads (45%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.003); catalogued as rs782514310, COSV100129961; called by muse, mutect2, varscan2
- HCST | c.108A>G p.S36= | Splice Region (SNP) | VAF 10/28 reads (36%) | catalogued as COSV99385726, COSV99385738; called by muse, mutect2, varscan2
- HDLBP | c.206G>A p.R69Q | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT tolerated (0.18); PolyPhen benign (0.065); catalogued as rs764118724, COSV100190797; called by muse, mutect2, varscan2
- HECTD4 | c.8063G>A p.R2688H | Missense Mutation (SNP) | VAF 37/88 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); catalogued as COSV66388665; called by muse, mutect2, varscan2
- HLA-C | c.698A>G p.Y233C | Missense Mutation (SNP) | VAF 72/189 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV66111568; called by muse, mutect2, varscan2
- HLA-G | c.644A>G p.H215R | Missense Mutation (SNP) | VAF 108/227 reads (48%) | SIFT tolerated, low confidence (0.14); PolyPhen possibly damaging (0.54); catalogued as COSV100827208; called by muse, mutect2, varscan2
- HMBOX1 | c.1172C>T p.A391V | Missense Mutation (SNP) | VAF 52/69 reads (75%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.935); catalogued as COSV55073396; called by muse, mutect2, varscan2
- HSH2D | c.133G>A p.E45K | Missense Mutation (SNP) | VAF 27/52 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs770936437, COSV53737889; called by muse, mutect2, varscan2
- HSPG2 | c.3196C>T p.R1066W | Missense Mutation (SNP) | VAF 63/150 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs145498664, COSV101021296; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- IARS2 | c.1885G>A p.G629R | Missense Mutation (SNP) | VAF 28/49 reads (57%) | SIFT tolerated (0.51); PolyPhen probably damaging (1); catalogued as rs754840461, COSV100228643; called by muse, mutect2, varscan2
- IGHV1-58 | c.238G>A p.A80T | Missense Mutation (SNP) | VAF 52/153 reads (34%) | SIFT tolerated (0.19); PolyPhen benign (0.177); catalogued as rs369851071; called by muse, mutect2, varscan2
- IGKV1D-16 | c.154A>G p.S52G | Missense Mutation (SNP) | VAF 89/224 reads (40%) | SIFT tolerated (0.32); PolyPhen benign (0.013); catalogued as rs570138575; called by muse, mutect2, varscan2
- IL21R | c.1549dup p.R517Pfs*48 | Frame Shift Ins (INS) | VAF 26/58 reads (45%) | catalogued as rs748992699; called by mutect2, varscan2
- IL33 | c.167A>G p.E56G | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.08); catalogued as COSV101197922; called by muse, mutect2, varscan2
- INSM2 | c.1605dup p.S536* | Frame Shift Ins (INS) | VAF 39/94 reads (41%) | catalogued as rs756928018; called by mutect2, varscan2
- INTS11 | c.320A>G p.Y107C | Missense Mutation (SNP) | VAF 39/80 reads (49%) | SIFT tolerated (0.09); PolyPhen benign (0.158); catalogued as rs1329765477, COSV100028686; called by muse, mutect2, varscan2
- IQCD | c.568C>A p.L190I | Missense Mutation (SNP) | VAF 35/82 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.729); catalogued as COSV100232521; called by muse, mutect2, varscan2
- IRX3 | c.706dup p.E236Gfs*12 | Frame Shift Ins (INS) | VAF 20/47 reads (43%) | catalogued as rs761463912; called by mutect2, varscan2
- IRX5 | c.499G>A p.A167T | Missense Mutation (SNP) | VAF 59/133 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100316024; called by muse, mutect2, varscan2
- ISYNA1 | c.416-2A>G p.X139_splice | Splice Site (SNP) | VAF 9/14 reads (64%) | catalogued as rs767101089, COSV99526359; called by muse, varscan2
- ITGAL | c.2968G>A p.V990M | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as rs181096180, COSV100776364; called by muse, mutect2, varscan2
- ITIH3 | c.1044G>T p.R348S | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0.009); catalogued as COSV101407164; called by muse, mutect2, varscan2
- ITPR1 | c.6964G>A p.A2322T (on ENST00000354582; = p.A2267T on NM_002222.7) | Missense Mutation (SNP) | VAF 29/63 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.017); catalogued as COSV100233335; called by muse, mutect2, varscan2
- ITPR2 | c.2795T>C p.V932A | Missense Mutation (SNP) | VAF 48/100 reads (48%) | SIFT tolerated (0.29); PolyPhen benign (0.265); catalogued as COSV101190021, COSV101190192; called by muse, mutect2, varscan2
- ITPRIPL1 | c.731dup p.Q245Tfs*32 (on ENST00000439118 / NM_001008949.3; = p.Q253Tfs*32 on NM_178495.6) | Frame Shift Ins (INS) | VAF 33/80 reads (41%) | catalogued as rs749417016; called by mutect2, pindel, varscan2
- JMY | c.2064+2T>C p.X688_splice | Splice Site (SNP) | VAF 40/114 reads (35%) | catalogued as COSV101268128; called by muse, mutect2, varscan2
- KANSL1 | c.1431+2T>C p.X477_splice | Splice Site (SNP) | VAF 21/88 reads (24%) | catalogued as COSV99294982; called by muse, mutect2, varscan2
- KATNBL1 | c.791A>T p.N264I | Missense Mutation (SNP) | VAF 39/80 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99854552; called by muse, mutect2, varscan2
- KCNB2 | c.435del p.E146Nfs*3 | Frame Shift Del (DEL) | VAF 32/82 reads (39%) | catalogued as rs752059864; called by mutect2, varscan2
- KCNQ5 | c.2468C>T p.P823L | Missense Mutation (SNP) | VAF 32/66 reads (48%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.011); catalogued as COSV100573256; called by muse, mutect2, varscan2
- KDM6A | c.3331C>T p.R1111C | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as rs763592177, COSV65038074, COSV65038305, COSV65040911, COSV65042699; called by muse, mutect2, varscan2
- KIAA0319L | c.386T>C p.V129A | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as COSV100357739, COSV57851364; called by muse, mutect2, varscan2
- KIAA0408 | c.562C>T p.R188W | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as rs186474406; called by muse, mutect2, varscan2
- KIFC2 | c.2435C>T p.P812L | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs768022702, COSV100023876; called by muse, varscan2
- KLF10 | c.1241A>G p.D414G | Missense Mutation (SNP) | VAF 54/88 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99574964; called by muse, mutect2, varscan2
- KPRP | c.64T>C p.S22P | Missense Mutation (SNP) | VAF 5/112 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.01); catalogued as COSV100908815; called by muse, mutect2
- L1TD1 | c.148G>T p.A50S | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.157); catalogued as COSV100776632; called by muse, varscan2
- LAMC3 | c.740A>G p.D247G | Missense Mutation (SNP) | VAF 30/90 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); catalogued as COSV100736107; called by muse, mutect2, varscan2
- LAMP1 | c.160T>C p.Y54H | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100208786; called by muse, mutect2, varscan2
- LARP1 | c.906dup p.T303Hfs*19 (on ENST00000518297 / NM_033551.3; = p.T226Hfs*19 on NM_015315.5 and 6 other RefSeq transcripts) | Frame Shift Ins (INS) | VAF 44/81 reads (54%) | catalogued as rs769338468; called by mutect2, varscan2
- LARP7 | c.1643G>A p.R548Q | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs373823878, COSV60521172; called by muse, mutect2, varscan2
- LATS2 | c.2545C>T p.R849W | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); catalogued as rs778450722, COSV101231681; called by muse, mutect2, varscan2
- LIMS2 | c.440T>C p.I147T (on ENST00000355119 / NM_001161403.3; = p.I171T on NM_017980.4) | Missense Mutation (SNP) | VAF 33/84 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.419); catalogued as COSV99760788; called by muse, mutect2
- LRIF1 | c.359T>C p.V120A | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated (0.77); PolyPhen benign (0.078); catalogued as COSV100870937; called by muse, mutect2, varscan2
- LRIG1 | c.3037G>A p.A1013T | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); catalogued as COSV99834494; called by muse, mutect2, varscan2
- LRP1 | c.12575dup p.D4193Rfs*9 | Frame Shift Ins (INS) | VAF 35/77 reads (45%) | catalogued as rs757410385; called by mutect2, varscan2
- LRP2 | c.4564A>G p.N1522D | Missense Mutation (SNP) | VAF 39/89 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.723); catalogued as COSV99790426; called by muse, mutect2, varscan2
- LUZP2 | c.122T>C p.I41T | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); catalogued as COSV100421100, COSV100421500; called by muse, mutect2, varscan2
- LZTS3 | c.958C>T p.L320F | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT tolerated (0.16); PolyPhen benign (0.07); catalogued as rs747358450, COSV100232397; called by muse, varscan2
- MAGEE2 | c.94T>C p.S32P | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT tolerated, low confidence (0.13); PolyPhen probably damaging (0.969); catalogued as COSV100973224; called by muse, mutect2, varscan2
- MAP3K4 | c.3040T>C p.S1014P | Missense Mutation (SNP) | VAF 10/166 reads (6%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV100815706; called by muse, mutect2
- MAP4K2 | c.787A>G p.T263A | Missense Mutation (SNP) | VAF 39/93 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.349); catalogued as COSV99581812; called by muse, mutect2, varscan2
- MAPK13 | c.860A>G p.K287R | Missense Mutation (SNP) | VAF 4/47 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.025); catalogued as COSV99275626; called by muse, mutect2
- MAST2 | c.2246A>G p.E749G | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.297); catalogued as COSV100788819; called by muse, mutect2, varscan2
- MBD6 | c.2345dup p.A783Sfs*10 | Frame Shift Ins (INS) | VAF 26/46 reads (57%) | catalogued as rs746267361; called by mutect2, varscan2
- MCM5 | c.790A>G p.T264A | Missense Mutation (SNP) | VAF 37/80 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.265); catalogued as COSV99332042; called by muse, mutect2, varscan2
- MCTP1 | c.1210A>T p.K404* | Nonsense Mutation (SNP) | VAF 17/40 reads (43%) | catalogued as COSV100388300; called by muse, mutect2, varscan2
- MDM1 | c.1172A>G p.D391G | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100292079; called by muse, mutect2
- MED13 | c.5626T>A p.W1876R | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101181431, COSV67264454; called by muse, mutect2, varscan2
- MFSD2A | c.403T>A p.S135T (on ENST00000372809 / NM_001136493.3; = p.S122T on NM_032793.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT tolerated (0.68); PolyPhen possibly damaging (0.612); catalogued as COSV100861741; called by muse, mutect2, varscan2
- MIDEAS | c.2611T>C p.Y871H | Missense Mutation (SNP) | VAF 77/163 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99679271; called by muse, mutect2, varscan2
- MINK1 | c.318G>T p.E106D | Missense Mutation (SNP) | VAF 33/96 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV100767298; called by muse, mutect2, varscan2
- MINPP1 | c.1142T>C p.M381T | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); catalogued as rs755848341, COSV100916791; called by muse, mutect2, varscan2
- MNT | c.716G>A p.C239Y | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV99438364; called by muse, mutect2, varscan2
- MORF4L2 | c.558A>G p.I186M | Missense Mutation (SNP) | VAF 36/69 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100846400; called by muse, mutect2, varscan2
- MORN5 | c.479A>G p.K160R | Missense Mutation (SNP) | VAF 31/79 reads (39%) | SIFT tolerated (0.19); PolyPhen benign (0.012); catalogued as COSV100493621; called by muse, mutect2, varscan2
- MSH6 | c.3935T>C p.V1312A | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV99317021; called by muse, mutect2, varscan2
- MSLNL | c.279+7G>A | Splice Region (SNP) | VAF 48/134 reads (36%) | catalogued as rs529654446, COSV99558816; called by muse, mutect2, varscan2
- MTCL1 | c.3251dup p.H1085Sfs*11 (on ENST00000306329 / NM_001378206.1; = p.H766Sfs*11 on NM_015210.4) | Frame Shift Ins (INS) | VAF 33/82 reads (40%) | catalogued as rs1409748030; called by mutect2, pindel, varscan2
- MTM1 | c.1666C>T p.R556C | Missense Mutation (SNP) | VAF 29/72 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.836); catalogued as COSV100080726; called by muse, mutect2, varscan2
- MTMR9 | c.1363A>G p.M455V | Missense Mutation (SNP) | VAF 33/115 reads (29%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV99644630; called by muse, mutect2, varscan2
- MUC4 | c.13595A>G p.D4532G (on ENST00000463781 / NM_018406.7; = p.D296G on NM_004532.6) | Missense Mutation (SNP) | VAF 57/132 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.19); catalogued as COSV100206668; called by muse, mutect2, varscan2
- MYO10 | c.3188T>C p.L1063P | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.017); catalogued as COSV99946365; called by muse, mutect2, varscan2
- MYO16 | c.2525dup p.Q843Pfs*12 | Frame Shift Ins (INS) | VAF 16/42 reads (38%) | catalogued as rs761471964; called by mutect2, varscan2
- MYO18B | c.6067T>C p.Y2023H | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV59142347; called by muse, mutect2, varscan2
- MYO9A | c.5743G>C p.D1915H | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as COSV100614396; called by muse, mutect2, varscan2
- MYO9A | c.2004T>G p.N668K | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100614405; called by muse, mutect2, varscan2
- MYRF | c.789dup p.S264Qfs*74 (on ENST00000278836 / NM_001127392.3; = p.S255Qfs*74 on NM_013279.4) | Frame Shift Ins (INS) | VAF 46/94 reads (49%) | catalogued as rs769274302; called by mutect2, varscan2
- NADSYN1 | c.43T>C p.W15R | Missense Mutation (SNP) | VAF 46/107 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100035079; called by muse, mutect2, varscan2
- NCAPD3 | c.2386A>T p.S796C | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT tolerated (0.06); PolyPhen benign (0.112); catalogued as COSV101599403; called by muse, mutect2, varscan2
- NCKAP1 | c.461A>G p.K154R | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT tolerated (0.19); PolyPhen benign (0.204); catalogued as rs779215853, COSV100720576; called by muse, mutect2, varscan2
- NCKAP5 | c.4457A>G p.K1486R | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.084); catalogued as COSV100494552; called by muse, mutect2, varscan2
- NECTIN2 | c.1099G>A p.A367T | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.995); catalogued as rs1188434646, COSV52977543; called by muse, mutect2, varscan2
- NECTIN3 | c.1416dup p.E473Rfs*12 | Frame Shift Ins (INS) | VAF 9/27 reads (33%) | catalogued as rs760367541; called by mutect2, varscan2
- NEIL2 | c.689-2A>G p.X230_splice | Splice Site (SNP) | VAF 100/145 reads (69%) | catalogued as rs749910147, COSV99462563; called by muse, mutect2, varscan2
- NEK1 | c.425T>A p.V142E | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV101455904; called by muse, mutect2, varscan2
- NELFCD | c.604A>G p.T202A (on ENST00000602795; = p.T184A on NM_198976.4) | Missense Mutation (SNP) | VAF 38/93 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as COSV100683000; called by muse, mutect2, varscan2
- NF1 | c.8376A>G p.P2792= (on ENST00000358273 / NM_001042492.3; = p.P2771= on NM_000267.3) | Splice Region (SNP) | VAF 21/56 reads (38%) | catalogued as COSV100648376; called by muse, mutect2, varscan2
- NIPA2 | c.98dup p.L35Pfs*21 | Frame Shift Ins (INS) | VAF 20/38 reads (53%) | catalogued as rs145147241; called by mutect2, varscan2
- NIPSNAP1 | c.356A>G p.Q119R | Missense Mutation (SNP) | VAF 8/85 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV99331327; called by muse, mutect2
- NKX2-2 | c.553C>T p.R185C | Missense Mutation (SNP) | VAF 75/184 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65819533; called by muse, mutect2, varscan2
- NLRC4 | c.3065T>C p.V1022A | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.063); catalogued as COSV99250154; called by muse, mutect2, varscan2
- NOS3 | c.1712C>A p.T571N | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99872225; called by muse, mutect2, varscan2
- NOTCH2 | c.4769A>G p.Y1590C | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.807); catalogued as COSV99866964; called by muse, mutect2, varscan2
- NPAS2 | c.707A>G p.Q236R | Missense Mutation (SNP) | VAF 40/108 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV100177050; called by muse, mutect2, varscan2
- NPAS3 | c.1202A>G p.K401R (on ENST00000356141 / NM_001164749.2; = p.K369R on NM_022123.3) | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.651); catalogued as COSV100640741; called by muse, mutect2, varscan2
- NUP214 | c.4133dup p.V1379Gfs*60 | Frame Shift Ins (INS) | VAF 16/42 reads (38%) | catalogued as rs780417788; called by mutect2, varscan2
- OBSCN | c.22949G>A p.S7650N | Missense Mutation (SNP) | VAF 33/96 reads (34%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV100805931; called by muse, mutect2, varscan2
- OLFML2A | c.1739T>C p.L580P | Missense Mutation (SNP) | VAF 36/82 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV99992910; called by muse, mutect2, varscan2
- OR10AG1 | c.128A>G p.H43R | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as COSV100400220; called by muse, mutect2, varscan2
- OR2AE1 | c.446G>A p.W149* | Nonsense Mutation (SNP) | VAF 23/54 reads (43%) | catalogued as COSV100318415; called by muse, mutect2, varscan2
- OR2T8 | c.272C>T p.S91F | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100178510; called by muse, mutect2, varscan2
- OR4K2 | c.176T>A p.M59K | Missense Mutation (SNP) | VAF 60/299 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs768569355, COSV100064791; called by muse, mutect2, varscan2
- OR5D13 | c.629T>C p.V210A | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT tolerated (0.31); PolyPhen benign (0.02); catalogued as COSV100687081; called by muse, mutect2, varscan2
- OR5L2 | c.215G>C p.C72S | Missense Mutation (SNP) | VAF 60/119 reads (50%) | SIFT tolerated (0.05); PolyPhen benign (0.081); catalogued as COSV101004421; called by muse, mutect2, varscan2
- OR5M1 | c.881A>G p.N294S | Missense Mutation (SNP) | VAF 31/64 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV101591614; called by muse, mutect2, varscan2
- OR5M10 | c.24A>G p.I8M | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV101595925; called by muse, mutect2, varscan2
- OSBPL11 | c.1295A>G p.Y432C | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99954548; called by muse, mutect2, varscan2
- P2RX3 | c.938C>T p.A313V | Missense Mutation (SNP) | VAF 42/86 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99629001; called by muse, mutect2, varscan2
- PAQR5 | c.112T>G p.C38G | Missense Mutation (SNP) | VAF 47/101 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); catalogued as COSV100575629; called by muse, mutect2, varscan2
- PARP1 | c.2903A>G p.D968G | Missense Mutation (SNP) | VAF 34/73 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0.05); catalogued as rs199689226, COSV100829066; called by muse, mutect2, varscan2
- PATJ | c.3212T>C p.I1071T | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100335080; called by muse, mutect2, varscan2
- PCDH11X | c.2815T>C p.Y939H | Missense Mutation (SNP) | VAF 45/96 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53501417; called by muse, mutect2, varscan2
- PCDHB12 | c.787A>G p.T263A | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.012); catalogued as COSV99507892; called by muse, mutect2, varscan2
- PCDHB13 | c.197G>T p.R66M | Missense Mutation (SNP) | VAF 34/95 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.988); catalogued as COSV99507898; called by muse, varscan2
- PCDHGA3 | c.1430A>G p.Q477R | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.006); catalogued as rs775001593, COSV53910964; called by muse, mutect2, varscan2
- PCDHGB3 | c.1831G>A p.A611T | Missense Mutation (SNP) | VAF 43/151 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs1326941167, COSV99547728; called by muse, mutect2, varscan2
- PCDHGB5 | c.1715A>G p.D572G | Missense Mutation (SNP) | VAF 55/117 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.325); catalogued as rs749737928; called by muse, mutect2, varscan2
- PCDHGB7 | c.989G>A p.R330Q | Missense Mutation (SNP) | VAF 31/72 reads (43%) | SIFT tolerated (0.62); PolyPhen benign (0.003); catalogued as rs770294020, COSV53919060, COSV53945961; called by muse, mutect2, varscan2
- PCDHGC4 | c.1679A>T p.D560V | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99342501; called by muse, mutect2
- PDCD11 | c.1550T>G p.L517R | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100874426; called by muse, mutect2, varscan2
- PDCD6IP | c.602del p.L201* | Frame Shift Del (DEL) | VAF 9/36 reads (25%) | catalogued as rs781474699; called by mutect2, varscan2
- PDIA2 | c.1108G>T p.G370C | Missense Mutation (SNP) | VAF 30/91 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764426526, COSV99250358; called by muse, mutect2, varscan2
- PFKP | c.701C>T p.A234V | Missense Mutation (SNP) | VAF 7/114 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66896529; called by muse, mutect2
- PHACTR4 | c.1369A>G p.S457G (on ENST00000373839 / NM_001350159.2; = p.S467G on NM_023923.4) | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100868499; called by muse, mutect2, varscan2
- PHC1 | c.170T>C p.M57T | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV101418715; called by muse, mutect2, varscan2
- PHF2 | c.1475dup p.T493Dfs*21 | Frame Shift Ins (INS) | VAF 12/34 reads (35%) | catalogued as rs769717544; called by mutect2, varscan2
- PIKFYVE | c.1555G>T p.V519L | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT tolerated (0.42); PolyPhen benign (0.04); catalogued as COSV100011512; called by muse, mutect2, varscan2
- PJVK | c.677T>G p.V226G | Missense Mutation (SNP) | VAF 27/62 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.168); catalogued as COSV100910563; called by muse, mutect2, varscan2
- PKD1 | c.7864-2A>G p.X2622_splice | Splice Site (SNP) | VAF 15/176 reads (9%) | catalogued as COSV99239129; called by muse, mutect2
- PKD1L1 | c.3335A>G p.N1112S | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.806); catalogued as COSV99221486; called by muse, mutect2, varscan2
- PLA2G3 | c.472T>C p.W158R | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99311697; called by muse, mutect2, varscan2
- PLA2G6 | c.512T>C p.L171P | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100140740; called by muse, mutect2, varscan2
- PLCL1 | c.1199T>C p.M400T | Missense Mutation (SNP) | VAF 26/46 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101407303; called by muse, mutect2, varscan2
- PLEKHG2 | c.3674G>T p.G1225V | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.448); catalogued as COSV99218216; called by muse, mutect2, varscan2
- PLVAP | c.47dup p.S17Qfs*106 | Frame Shift Ins (INS) | VAF 14/57 reads (25%) | catalogued as rs768884250; called by mutect2, pindel, varscan2
- PMS2 | c.2206G>T p.E736* | Nonsense Mutation (SNP) | VAF 37/87 reads (43%) | catalogued as COSV99764590; called by muse, mutect2, varscan2
- POGK | c.470A>G p.D157G | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.977); catalogued as COSV100902613; called by muse, mutect2, varscan2
- POLL | c.410+2T>C p.X137_splice | Splice Site (SNP) | VAF 24/48 reads (50%) | catalogued as COSV100150482; called by muse, mutect2, varscan2
- PPP1R12A | c.3092A>T p.*1031Lext*71 | Nonstop Mutation (SNP) | VAF 12/29 reads (41%) | catalogued as rs1565731811, COSV54108019, COSV54108277; called by muse, mutect2
- PPP1R12B | c.2861A>C p.K954T | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99295348; called by muse, mutect2, varscan2
- PPP2R2B | c.1190dup p.K398Qfs*15 (on ENST00000394409; = p.K464Qfs*15 on NM_181674.2) | Frame Shift Ins (INS) | VAF 27/75 reads (36%) | catalogued as rs767808084; called by mutect2, pindel, varscan2
- PPP2R3B | c.593A>G p.K198R | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.449); catalogued as rs1333979970, COSV101065609; called by muse, mutect2, varscan2
- PREPL | c.796A>G p.T266A | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.934); catalogued as rs756130943, COSV99576526; called by muse, mutect2, varscan2
- PRKN | c.200T>A p.V67D | Missense Mutation (SNP) | VAF 29/59 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100631422; called by muse, mutect2, varscan2
- PRRG1 | c.401dup p.P135Tfs*3 | Frame Shift Ins (INS) | VAF 24/74 reads (32%) | catalogued as rs781858060, COSV66158042; called by mutect2, varscan2
- PRSS35 | c.976A>G p.S326G | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.629); catalogued as COSV100864157; called by muse, varscan2
- PTEN | c.800dup p.D268Gfs*30 | Frame Shift Ins (INS) | VAF 48/78 reads (62%) | catalogued as COSV64302388; called by mutect2, pindel, varscan2
- PTK2 | c.1777T>C p.S593P | Missense Mutation (SNP) | VAF 52/77 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100571291; called by muse, mutect2, varscan2
- PTPN22 | c.92T>C p.L31P | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100703997; called by muse, mutect2, varscan2
- PTPRN2 | c.2326T>C p.S776P | Missense Mutation (SNP) | VAF 49/129 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.019); catalogued as rs768237724, COSV101235408; called by muse, mutect2
- PXDNL | c.2590C>T p.R864C | Missense Mutation (SNP) | VAF 69/93 reads (74%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs936865843, COSV62476590; called by muse, mutect2, varscan2
- RAB18 | c.445+2T>C p.X149_splice | Splice Site (SNP) | VAF 35/75 reads (47%) | catalogued as COSV100803900; called by muse, mutect2, varscan2
- RAB37 | c.238A>G p.K80E (on ENST00000392613 / NM_001006638.3; = p.K73E on NM_175738.5) | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV100463769; called by muse, mutect2, varscan2
- RABEP2 | c.1409A>G p.Q470R | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.269); catalogued as COSV100707234; called by muse, mutect2, varscan2
- RABGEF1 | c.898A>C p.K300Q (on ENST00000439720 / NM_001287061.2; = p.K287Q on NM_014504.3 and 29 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 38/82 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99535168; called by muse, mutect2, varscan2
- RAD54L | c.316C>T p.R106C | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs145938974; called by muse, mutect2, varscan2
- RAG1 | c.1359G>T p.E453D | Missense Mutation (SNP) | VAF 26/50 reads (52%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.965); catalogued as rs1178216516, COSV100201187; called by muse, mutect2, varscan2
- RBM34 | c.203A>G p.Q68R | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT tolerated (0.36); PolyPhen benign (0.006); catalogued as COSV100784078; called by muse, mutect2, varscan2
- RBM41 | c.398G>A p.R133H | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.538); catalogued as rs769714202, COSV99179841; called by muse, mutect2, varscan2
- RELB | c.1636G>C p.D546H | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.667); catalogued as COSV99672678, COSV99673169; called by muse, mutect2, varscan2
- REV1 | c.455A>T p.D152V | Missense Mutation (SNP) | VAF 39/95 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.029); catalogued as COSV99301530; called by muse, mutect2, varscan2
- REV3L | c.4523A>G p.Q1508R | Missense Mutation (SNP) | VAF 10/107 reads (9%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.003); catalogued as rs559546908, COSV100725713; called by muse, mutect2
- RIF1 | c.7036A>G p.I2346V | Missense Mutation (SNP) | VAF 24/43 reads (56%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.848); catalogued as COSV99691314; called by muse, mutect2, varscan2
- RIOK1 | c.189_191dup p.D69dup | In Frame Ins (INS) | VAF 21/63 reads (33%) | catalogued as rs764932797; called by mutect2, pindel, varscan2
- RIOK3 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 13/110 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as COSV100259466; called by muse, mutect2, varscan2
- RNMT | c.1103T>C p.V368A | Missense Mutation (SNP) | VAF 9/121 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.895); catalogued as COSV100054976; called by muse, mutect2
- RPH3AL | c.106T>C p.Y36H | Missense Mutation (SNP) | VAF 59/128 reads (46%) | SIFT tolerated (0.5); PolyPhen benign (0.27); catalogued as rs762293596, COSV100047953; called by muse, mutect2, varscan2
- RPP14 | c.176T>A p.L59* | Nonsense Mutation (SNP) | VAF 12/36 reads (33%) | catalogued as COSV99916786; called by muse, mutect2, varscan2
- RPP25L | c.98G>A p.G33D | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99427072; called by muse, mutect2, varscan2
- RRAGB | c.40A>T p.N14Y | Missense Mutation (SNP) | VAF 42/79 reads (53%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.979); catalogued as COSV99469662; called by muse, mutect2, varscan2
- RRH | c.324dup p.G109Wfs*23 | Frame Shift Ins (INS) | VAF 23/74 reads (31%) | catalogued as rs751964437; called by mutect2, varscan2
- RSF1 | c.1158A>C p.K386N | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100408029; called by muse, mutect2, varscan2
- RTEL1 | c.2951T>C p.I984T | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.013); catalogued as COSV100542861; called by muse, mutect2, varscan2
- SAMHD1 | c.1084A>C p.M362L | Missense Mutation (SNP) | VAF 26/46 reads (57%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.888); catalogued as COSV99484359; called by muse, mutect2, varscan2
- SAR1B | c.225T>A p.D75E | Missense Mutation (SNP) | VAF 32/55 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs778699172, COSV101284201; called by muse, mutect2, varscan2
- SART3 | c.1165G>A p.A389T (on ENST00000228284; = p.A371T on NM_014706.4) | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1191290503, COSV57209319; called by muse, mutect2, varscan2
- SCO2 | c.536G>A p.R179H | Missense Mutation (SNP) | VAF 70/147 reads (48%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.89); catalogued as rs149750715; called by muse, mutect2, varscan2
- SCYL2 | c.1319C>A p.T440N | Missense Mutation (SNP) | VAF 28/57 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.889); catalogued as COSV100675318; called by muse, mutect2, varscan2
- SETX | c.5243dup p.L1750Ffs*8 | Frame Shift Ins (INS) | VAF 16/31 reads (52%) | catalogued as rs754706851; called by mutect2, varscan2
- SH3GL3 | c.494G>A p.R165H | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs955535846, COSV61059760, COSV61062546; called by muse, mutect2, varscan2
- SHOC1 | c.3679G>T p.E1227* | Nonsense Mutation (SNP) | VAF 23/49 reads (47%) | catalogued as COSV100598067; called by muse, mutect2, varscan2
- SHPRH | c.682A>G p.S228G | Missense Mutation (SNP) | VAF 42/81 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV99262744; called by muse, mutect2, varscan2
- SIGLECL1 | c.77G>T p.S26I | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.234); catalogued as COSV100324018; called by muse, mutect2, varscan2
- SIPA1L2 | c.4147A>G p.M1383V | Missense Mutation (SNP) | VAF 40/98 reads (41%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs745521843, COSV99479808; called by muse, mutect2, varscan2
- SIPA1L3 | c.5078T>C p.L1693P | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.972); catalogued as COSV99730611; called by muse, varscan2
- SLC11A2 | c.822T>G p.C274W (on ENST00000394904 / NM_001379455.1; = p.C245W on NM_000617.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 40/93 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100015136; called by muse, mutect2, varscan2
- SLC12A3 | c.742-2A>G p.X248_splice | Splice Site (SNP) | VAF 34/72 reads (47%) | catalogued as COSV99344847; called by muse, mutect2, varscan2
- SLC28A2 | c.1964C>T p.T655I | Missense Mutation (SNP) | VAF 9/155 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.646); catalogued as COSV100754827; called by muse, mutect2
- SLC46A3 | c.44T>C p.F15S | Missense Mutation (SNP) | VAF 44/84 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57179972; called by muse, mutect2, varscan2
- SLC4A9 | c.944T>C p.F315S (on ENST00000507527 / NM_001258428.2; = p.F291S on NM_031467.3) | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99140014; called by muse, mutect2, varscan2
- SLC5A3 | c.2125G>T p.G709* | Nonsense Mutation (SNP) | VAF 47/112 reads (42%) | catalogued as COSV100758106; called by muse, mutect2, varscan2
- SLCO1B3 | c.833del p.F278Sfs*22 | Frame Shift Del (DEL) | VAF 61/154 reads (40%) | catalogued as rs751405974; called by mutect2, varscan2
- SLCO4A1 | c.1636A>C p.K546Q | Missense Mutation (SNP) | VAF 46/130 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0.065); catalogued as COSV99415170; called by muse, mutect2, varscan2
- SLFN11 | c.1858T>C p.F620L | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.444); catalogued as COSV100391056; called by muse, mutect2, varscan2
- SMARCA4 | c.810dup p.G271Rfs*16 | Frame Shift Ins (INS) | VAF 18/63 reads (29%) | catalogued as rs1165714406; called by mutect2, pindel, varscan2
- SMARCA4 | c.1561C>T p.R521W | Missense Mutation (SNP) | VAF 31/71 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60786176; called by muse, mutect2, varscan2
- SMPD4 | c.1933G>A p.E645K (on ENST00000409031 / NM_017951.4; = p.E616K on NM_017751.4) | Missense Mutation (SNP) | VAF 59/146 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.101); catalogued as rs924505708, COSV100302630; called by muse, mutect2, varscan2
- SND1 | c.7T>C p.S3P | Missense Mutation (SNP) | VAF 75/194 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.307); catalogued as COSV100691195; called by muse, mutect2, varscan2
- SNRPN | c.381G>T p.L127F | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100578677; called by muse, mutect2, varscan2
- SNX14 | c.2378A>G p.Y793C (on ENST00000314673 / NM_001350535.1; = p.Y740C on NM_020468.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV100121806; called by muse, mutect2, varscan2
- SNX32 | c.850G>A p.D284N | Missense Mutation (SNP) | VAF 28/60 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.225); catalogued as rs150293421; called by muse, mutect2, varscan2
- SORCS1 | c.2813A>T p.E938V | Missense Mutation (SNP) | VAF 15/106 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.737); catalogued as COSV99550712; called by muse, mutect2, varscan2
- SPRED1 | c.467T>C p.L156P | Missense Mutation (SNP) | VAF 40/91 reads (44%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV100136448; called by muse, mutect2, varscan2
- SPTBN5 | c.5941A>G p.K1981E | Missense Mutation (SNP) | VAF 47/120 reads (39%) | SIFT tolerated (0.25); PolyPhen benign (0.005); catalogued as COSV100312252; called by muse, mutect2, varscan2
- SRF | c.1154G>C p.S385T | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT tolerated (0.46); PolyPhen benign (0.267); catalogued as COSV99542001; called by muse, mutect2, varscan2
- SRRM2 | c.7237G>A p.A2413T | Missense Mutation (SNP) | VAF 29/82 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.062); catalogued as COSV99241242, COSV99241746; called by muse, mutect2, varscan2
- STAB2 | c.3158A>G p.Q1053R | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV101186382; called by muse, mutect2, varscan2
- STEAP3 | c.758C>T p.S253F | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV100713501; called by muse, mutect2, varscan2
- STK24 | c.327A>G p.I109M | Missense Mutation (SNP) | VAF 31/63 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV100925031; called by muse, mutect2, varscan2
- SUPT6H | c.515A>G p.E172G | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.49); PolyPhen benign (0.021); catalogued as COSV100112812; called by muse, mutect2, varscan2
- SVIL | c.5893G>T p.E1965* (on ENST00000355867 / NM_021738.3; = p.E1539* on NM_003174.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 35/69 reads (51%) | catalogued as COSV100881565, COSV63446693; called by muse, mutect2, varscan2
- SWAP70 | c.1127G>A p.R376H | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs200743817, COSV59665566; called by muse, varscan2
- SYCP1 | c.1009A>G p.T337A | Missense Mutation (SNP) | VAF 32/86 reads (37%) | SIFT tolerated (0.28); PolyPhen benign (0.019); catalogued as COSV101051215; called by muse, mutect2, varscan2
- SYCP2 | c.2362dup p.M788Nfs*23 | Frame Shift Ins (INS) | VAF 30/66 reads (45%) | catalogued as rs570102997; called by mutect2, varscan2
- SYK | c.1265A>G p.N422S | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT tolerated (0.28); PolyPhen benign (0.391); catalogued as COSV101002637; called by muse, mutect2, varscan2
- SYNPR | c.775A>G p.T259A | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs1224859519, COSV99889345; called by muse, mutect2, varscan2
- SZT2 | c.503T>C p.L168P | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100726335; called by muse, mutect2, varscan2
- TAC1 | c.215A>G p.D72G | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.601); catalogued as COSV100071232; called by muse, mutect2, varscan2
- TAF1 | c.1847T>A p.V616D (on ENST00000373790 / NM_138923.4; = p.V637D on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 39/88 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV99337137; called by muse, mutect2, varscan2
- TANC2 | c.3915C>G p.N1305K | Missense Mutation (SNP) | VAF 45/68 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101267572, COSV101267687; called by muse, mutect2, varscan2
- TBCK | c.2362A>T p.K788* (on ENST00000273980 / NM_001163436.4; = p.K725* on NM_033115.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 81/186 reads (44%) | catalogued as COSV99913232; called by muse, mutect2, varscan2
- TCF20 | c.3036T>A p.F1012L | Missense Mutation (SNP) | VAF 31/75 reads (41%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV100166972; called by muse, mutect2, varscan2
- TENM3 | c.6926A>G p.N2309S | Missense Mutation (SNP) | VAF 30/56 reads (54%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV101305490; called by muse, mutect2, varscan2
- TIMP3 | c.602dup p.D202Gfs*2 | Frame Shift Ins (INS) | VAF 22/54 reads (41%) | catalogued as rs749890843; called by mutect2, varscan2
- TKTL1 | c.1573G>A p.A525T | Missense Mutation (SNP) | VAF 44/107 reads (41%) | SIFT tolerated (0.2); PolyPhen benign (0.219); catalogued as COSV99474202; called by muse, mutect2, varscan2
- TLE3 | c.1700G>A p.R567H | Missense Mutation (SNP) | VAF 36/90 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs1227732728, COSV58172366; called by muse, mutect2
- TLL1 | c.180G>T p.W60C | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV99289263; called by muse, mutect2, varscan2
- TLR4 | c.1918A>G p.S640G (on ENST00000355622 / NM_138554.5; = p.S600G on NM_003266.4) | Missense Mutation (SNP) | VAF 37/107 reads (35%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as COSV100842880; called by muse, mutect2, varscan2
- TMED1 | c.506T>C p.I169T | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT tolerated (0.45); PolyPhen benign (0.055); catalogued as COSV99284290; called by muse, mutect2, varscan2
- TMEM125 | c.340G>A p.A114T | Missense Mutation (SNP) | VAF 52/126 reads (41%) | SIFT tolerated (0.4); PolyPhen benign (0.014); catalogued as rs756819583, COSV101443218; called by muse, mutect2, varscan2
- TMEM82 | c.679T>C p.F227L | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV99606829; called by muse, mutect2, varscan2
- TNC | c.1889T>C p.V630A | Missense Mutation (SNP) | VAF 11/19 reads (58%) | SIFT tolerated (0.1); PolyPhen benign (0.217); catalogued as COSV100406337; called by muse, mutect2, varscan2
- TNFSF12-TNFSF13 | c.884-2A>G p.X295_splice | Splice Site (SNP) | VAF 55/97 reads (57%) | catalogued as COSV99547443; called by muse, mutect2, varscan2
- TNRC18 | c.4627dup p.R1543Pfs*10 | Frame Shift Ins (INS) | VAF 22/77 reads (29%) | catalogued as rs754233336; called by mutect2, varscan2
- TOPORS | c.1246T>C p.W416R | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.783); catalogued as COSV100745212; called by muse, mutect2, varscan2
- TRAK1 | c.2681T>C p.L894P | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.374); catalogued as COSV100565932; called by muse, mutect2, varscan2
- TREX2 | c.725T>C p.L242P (on ENST00000334497; = p.L199P on NM_080701.3) | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.871); catalogued as COSV100444341; called by muse, mutect2, varscan2
- TRPC6 | c.2567A>G p.Q856R | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.421); catalogued as COSV100723775; called by muse, mutect2, varscan2
- TRPV6 | c.1850T>C p.M617T | Missense Mutation (SNP) | VAF 52/92 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100844456; called by muse, mutect2, varscan2
- TTC37 | c.886A>C p.T296P | Missense Mutation (SNP) | VAF 74/144 reads (51%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.541); catalogued as COSV100706923; called by muse, mutect2, varscan2
- TTN | c.11477T>C p.L3826P (on ENST00000591111; = p.L3780P on NM_003319.4) | Missense Mutation (SNP) | VAF 16/33 reads (48%) | catalogued as COSV60348303; called by muse, mutect2, varscan2
- TUBB1 | c.277+2T>C p.X93_splice | Splice Site (SNP) | VAF 26/63 reads (41%) | catalogued as COSV99414259; called by muse, mutect2, varscan2
- UBR4 | c.2807T>C p.L936P | Missense Mutation (SNP) | VAF 36/79 reads (46%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.979); catalogued as COSV100921978; called by muse, mutect2, varscan2
- UFL1 | c.1978del p.R660Gfs*17 | Frame Shift Del (DEL) | VAF 15/48 reads (31%) | catalogued as rs750472217; called by mutect2, pindel, varscan2
- UGGT2 | c.3229-2A>G p.X1077_splice | Splice Site (SNP) | VAF 36/91 reads (40%) | catalogued as COSV100948966, COSV65077869; called by muse, mutect2, varscan2
- ULBP3 | c.212A>G p.K71R | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.376); catalogued as COSV100949664; called by muse, mutect2, varscan2
- UNC13B | c.4616A>G p.K1539R | Missense Mutation (SNP) | VAF 38/85 reads (45%) | SIFT tolerated (0.76); PolyPhen benign (0.017); catalogued as COSV100266916; called by muse, mutect2, varscan2
- UNC13C | c.6157A>G p.T2053A | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.001); catalogued as COSV99523387; called by muse, mutect2, varscan2
- UNC5A | c.1511G>T p.S504I | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV99459471; called by muse, mutect2, varscan2
- USP13 | c.2362A>C p.I788L | Missense Mutation (SNP) | VAF 30/72 reads (42%) | SIFT tolerated (0.36); PolyPhen benign (0.009); catalogued as COSV99831799; called by muse, mutect2, varscan2
- USP28 | c.2291C>T p.A764V | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT tolerated (0.3); PolyPhen benign (0.037); catalogued as rs780410860, COSV50156636; called by muse, mutect2, varscan2
- USP42 | c.2582C>T p.A861V | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1200471317, COSV100084942; called by muse, mutect2
- USP9X | c.1369G>A p.A457T | Missense Mutation (SNP) | VAF 34/82 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.579); catalogued as COSV100200145; called by muse, mutect2, varscan2
- VPS13A | c.4225A>G p.S1409G | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.039); catalogued as COSV100653576; called by muse, mutect2, varscan2
- VWA2 | c.1549C>A p.L517M | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.692); catalogued as COSV100074000; called by muse, mutect2, varscan2
- VWA3B | c.734A>G p.D245G | Missense Mutation (SNP) | VAF 32/86 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.541); catalogued as rs892387366; called by muse, mutect2, varscan2
- WDR73 | c.462G>T p.R154S | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.439); catalogued as COSV100822121; called by muse, mutect2, varscan2
- WDR91 | c.1633T>C p.W545R | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60369965; called by muse, mutect2, varscan2
- WNT6 | c.152A>T p.Q51L | Missense Mutation (SNP) | VAF 43/98 reads (44%) | SIFT tolerated (1); PolyPhen probably damaging (0.982); catalogued as COSV99293343; called by muse, mutect2, varscan2
- WRNIP1 | c.1459C>T p.R487* | Nonsense Mutation (SNP) | VAF 42/109 reads (39%) | catalogued as rs199966810, COSV66356153; called by muse, mutect2, varscan2
- WWC1 | c.2416T>G p.S806A | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV99516009; called by muse, mutect2
- XCR1 | c.763A>G p.I255V | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100499486; called by muse, mutect2, varscan2
- XPO7 | c.3208A>T p.N1070Y | Missense Mutation (SNP) | VAF 28/128 reads (22%) | SIFT tolerated (0.51); PolyPhen benign (0.005); catalogued as COSV99381499, COSV99382118; called by muse, mutect2, varscan2
- YY1AP1 | c.1165C>T p.R389W (on ENST00000295566 / NM_139118.2; = p.R332W on NM_018253.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 39/74 reads (53%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.649); catalogued as rs536088615, COSV55121748; called by muse, mutect2, varscan2
- ZCCHC14 | c.1826C>T p.A609V (on ENST00000268616; = p.A746V on NM_015144.3) | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.626); catalogued as COSV99234601; called by muse, mutect2, varscan2
- ZDBF2 | c.5624dup p.V1876Gfs*5 | Frame Shift Ins (INS) | VAF 12/32 reads (38%) | catalogued as rs770232797; called by mutect2, varscan2
- ZDHHC17 | c.641A>G p.N214S | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.798); catalogued as rs771135043, COSV100602306; called by muse, mutect2, varscan2
- ZDHHC5 | c.304C>T p.R102C | Missense Mutation (SNP) | VAF 35/71 reads (49%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.971); catalogued as COSV99762643; called by muse, mutect2, varscan2
- ZFAT | c.3718G>A p.A1240T | Missense Mutation (SNP) | VAF 82/122 reads (67%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); catalogued as COSV100914996; called by muse, mutect2, varscan2
- ZMYND10 | c.271A>G p.R91G | Missense Mutation (SNP) | VAF 31/83 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.021); catalogued as COSV99206061; called by muse, mutect2, varscan2
- ZNF106 | c.1969A>G p.T657A | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as COSV99783236; called by muse, mutect2
- ZNF326 | c.629T>C p.F210S | Missense Mutation (SNP) | VAF 35/75 reads (47%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.462); catalogued as COSV100438302; called by muse, mutect2, varscan2
- ZNF438 | c.2213A>G p.E738G | Missense Mutation (SNP) | VAF 37/78 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as COSV100062842; called by muse, mutect2, varscan2
- ZNF439 | c.688C>G p.L230V | Missense Mutation (SNP) | VAF 46/90 reads (51%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); catalogued as COSV58309010, COSV58309542; called by muse, mutect2, varscan2
- ZNF48 | c.1819A>G p.R607G | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); catalogued as COSV100198234; called by muse, mutect2, varscan2
- ZNF524 | c.174dup p.K59Qfs*31 | Frame Shift Ins (INS) | VAF 48/136 reads (35%) | catalogued as rs750719825; called by mutect2, varscan2
- ZNF570 | c.1516dup p.T506Nfs*37 | Frame Shift Ins (INS) | VAF 22/48 reads (46%) | catalogued as rs1203012118; called by mutect2, varscan2
- ZNF572 | c.18dup p.L7Tfs*7 | Frame Shift Ins (INS) | VAF 35/142 reads (25%) | catalogued as rs769734933; called by mutect2, varscan2
- ZNF574 | c.2335A>G p.T779A | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.835); catalogued as COSV99726568; called by muse, mutect2, varscan2
- ZNF577 | c.1154T>C p.L385P | Missense Mutation (SNP) | VAF 41/81 reads (51%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as COSV100031324; called by muse, mutect2, varscan2
- ZNF609 | c.2470C>T p.P824S | Missense Mutation (SNP) | VAF 26/49 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.104); catalogued as rs1419830766, COSV100441909; called by muse, mutect2, varscan2
- ZNF772 | c.527T>C p.L176P | Missense Mutation (SNP) | VAF 39/74 reads (53%) | SIFT tolerated (0.17); PolyPhen benign (0.116); catalogued as COSV100582940; called by muse, mutect2, varscan2
- ZNF793 | c.1145T>C p.L382P | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.645); catalogued as COSV101495708; called by muse, mutect2, varscan2
- ZZEF1 | c.4933C>T p.R1645* | Nonsense Mutation (SNP) | VAF 15/36 reads (42%) | catalogued as rs1262131601, COSV67557020; called by muse, mutect2
- ABCA9 | c.3425dup p.F1143Lfs*13 | Frame Shift Ins (INS) | VAF 16/43 reads (37%) | called by mutect2, pindel, varscan2
- ADAM10 | c.1258dup p.R420Kfs*9 | Frame Shift Ins (INS) | VAF 35/98 reads (36%) | called by mutect2, pindel, varscan2
- AFF4 | c.1862dup p.R622Sfs*10 | Frame Shift Ins (INS) | VAF 13/39 reads (33%) | called by mutect2, pindel, varscan2
- AMH | c.476dup p.E160Rfs*14 | Frame Shift Ins (INS) | VAF 28/74 reads (38%) | called by mutect2, pindel, varscan2
- ANAPC1 | c.5203-3dup | Splice Region (INS) | VAF 11/25 reads (44%) | called by mutect2, varscan2
- ARHGAP35 | c.3745dup p.V1249Gfs*18 | Frame Shift Ins (INS) | VAF 24/65 reads (37%) | called by mutect2, pindel, varscan2
- ARID5B | c.1489dup p.I497Nfs*31 | Frame Shift Ins (INS) | VAF 7/24 reads (29%) | called by mutect2, varscan2
- B3GNT5 | c.94dup p.W32Lfs*6 | Frame Shift Ins (INS) | VAF 40/100 reads (40%) | called by mutect2, varscan2
- BAG1 | c.941dup p.V315Gfs*9 | Frame Shift Ins (INS) | VAF 29/91 reads (32%) | called by mutect2, pindel, varscan2
- BMP8A | c.967dup p.Q323Pfs*9 | Frame Shift Ins (INS) | VAF 21/54 reads (39%) | called by mutect2, pindel, varscan2
- CBWD6 | c.646T>A p.L216I | Missense Mutation (SNP) | VAF 14/390 reads (4%) | SIFT tolerated (0.18); PolyPhen benign (0.06); called by muse, mutect2
- CCNK | c.336del p.K112Nfs*13 | Frame Shift Del (DEL) | VAF 33/84 reads (39%) | called by mutect2, pindel, varscan2
- CNTN6 | c.746del p.C249Ffs*104 | Frame Shift Del (DEL) | VAF 40/84 reads (48%) | called by mutect2, pindel, varscan2
- DDX17 | c.398dup p.N133Kfs*16 | Frame Shift Ins (INS) | VAF 12/29 reads (41%) | called by mutect2, varscan2
- DLEC1 | c.4676_4694del p.L1559Rfs*5 | Frame Shift Del (DEL) | VAF 30/69 reads (43%) | called by mutect2, pindel*, varscan2*
- DOCK1 | c.4086dup p.E1363Rfs*3 | Frame Shift Ins (INS) | VAF 31/63 reads (49%) | called by mutect2, pindel, varscan2
- EIF4G2 | c.2580del p.I861Lfs*13 | Frame Shift Del (DEL) | VAF 19/56 reads (34%) | called by mutect2, pindel, varscan2
- FEM1A | c.998dup p.E334Rfs*16 | Frame Shift Ins (INS) | VAF 58/163 reads (36%) | called by mutect2, pindel, varscan2
- GGNBP2 | c.260T>A p.V87D | Missense Mutation (SNP) | VAF 55/130 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.502); called by muse, mutect2, varscan2
- GPSM1 | c.608dup p.D204Rfs*37 | Frame Shift Ins (INS) | VAF 43/109 reads (39%) | called by mutect2, pindel, varscan2
- GRM8 | c.888dup p.L297Tfs*14 | Frame Shift Ins (INS) | VAF 38/78 reads (49%) | called by mutect2, varscan2
- GSDMD | c.608dup p.K204Efs*21 | Frame Shift Ins (INS) | VAF 32/169 reads (19%) | called by mutect2, pindel
- INTS4 | c.2264dup p.L755Ffs*14 | Frame Shift Ins (INS) | VAF 28/79 reads (35%) | called by mutect2, pindel, varscan2
- KMT2C | c.427del p.S143Vfs*3 | Frame Shift Del (DEL) | VAF 23/67 reads (34%) | called by mutect2, pindel, varscan2
- KPRP | c.1019dup p.Q341Tfs*6 | Frame Shift Ins (INS) | VAF 42/114 reads (37%) | called by mutect2, pindel, varscan2
- LCA5 | c.1730dup p.L577Ffs*12 | Frame Shift Ins (INS) | VAF 16/58 reads (28%) | called by mutect2, pindel, varscan2
- LDHC | c.686del p.N229Ifs*16 | Frame Shift Del (DEL) | VAF 22/55 reads (40%) | called by mutect2, pindel, varscan2
- LRRN3 | c.2071dup p.S691Kfs*84 | Frame Shift Ins (INS) | VAF 12/35 reads (34%) | called by mutect2, pindel, varscan2
- MAP3K1 | c.3236dup p.N1079Kfs*2 | Frame Shift Ins (INS) | VAF 11/33 reads (33%) | called by mutect2, pindel, varscan2
- NRG1 | c.909dup p.E304Rfs*12 (on ENST00000405005 / NM_013964.5; = p.E309Rfs*12 on NM_013956.5) | Frame Shift Ins (INS) | VAF 20/94 reads (21%) | called by mutect2, pindel, varscan2
- OSTN | c.160T>C p.S54P | Missense Mutation (SNP) | VAF 55/98 reads (56%) | SIFT tolerated (0.13); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PCARE | c.1032dup p.C346Mfs*3 | Frame Shift Ins (INS) | VAF 29/94 reads (31%) | called by mutect2, pindel, varscan2
- PDP1 | c.743_745del p.S248del | In Frame Del (DEL) | VAF 48/70 reads (69%) | called by mutect2, pindel, varscan2
- PPAT | c.401dup p.L135Afs*13 | Frame Shift Ins (INS) | VAF 10/46 reads (22%) | called by mutect2, pindel, varscan2
- RNF5 | c.526dup p.W176Lfs*27 | Frame Shift Ins (INS) | VAF 22/52 reads (42%) | called by mutect2, varscan2
- RNPEP | c.1665dup p.L556Tfs*26 | Frame Shift Ins (INS) | VAF 17/48 reads (35%) | called by mutect2, pindel, varscan2
- RPS6KB2 | c.1255dup p.R419Pfs*13 | Frame Shift Ins (INS) | VAF 26/64 reads (41%) | called by mutect2, pindel, varscan2
- SEMA3C | c.287_290del p.I96Kfs*22 | Frame Shift Del (DEL) | VAF 20/47 reads (43%) | called by pindel, varscan2
- SHPRH | c.495dup p.E166Rfs*7 | Frame Shift Ins (INS) | VAF 24/62 reads (39%) | called by mutect2, varscan2
- SMARCC2 | c.1754dup p.N586Efs*15 | Frame Shift Ins (INS) | VAF 49/137 reads (36%) | called by mutect2, pindel, varscan2
- SNED1 | c.3238dup p.L1080Pfs*124 | Frame Shift Ins (INS) | VAF 54/146 reads (37%) | called by mutect2, pindel, varscan2
- STN1 | c.84dup p.L29Tfs*51 | Frame Shift Ins (INS) | VAF 18/34 reads (53%) | called by mutect2, varscan2
- THOC2 | c.3992dup p.K1332Qfs*7 | Frame Shift Ins (INS) | VAF 24/63 reads (38%) | called by mutect2, pindel, varscan2
- TTF1 | c.263dup p.R89Efs*4 | Frame Shift Ins (INS) | VAF 51/115 reads (44%) | called by mutect2, pindel, varscan2
- XRCC4 | c.170A>G p.D57G | Missense Mutation (SNP) | VAF 4/71 reads (6%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.829); called by muse, mutect2
- ZFHX3 | c.5677_5678dup p.D1894Gfs*21 | Frame Shift Ins (INS) | VAF 38/108 reads (35%) | called by mutect2, varscan2
- ZNF280A | c.213_214insG p.S72Vfs*36 | Frame Shift Ins (INS) | VAF 63/124 reads (51%) | called by mutect2, pindel*, varscan2
- ZPBP2 | c.373dup p.T125Nfs*7 (on ENST00000348931 / NM_199321.3; = p.T103Nfs*7 on NM_198844.3) | Frame Shift Ins (INS) | VAF 17/43 reads (40%) | called by mutect2, pindel, varscan2
- ABCA13 | c.4278T>C p.D1426= | Silent (SNP) | VAF 5/58 reads (9%) | catalogued as COSV101329894; called by muse, mutect2
- ACOT7 | c.270G>A p.R90= (on ENST00000377855 / NM_181864.3; = p.R80= on NM_007274.4) | Silent (SNP) | VAF 22/53 reads (42%) | catalogued as rs763204698, COSV64113728; called by muse, mutect2, varscan2
- ACTL9 | c.543G>A p.S181= | Silent (SNP) | VAF 54/121 reads (45%) | catalogued as rs782083842, COSV61005467; called by muse, mutect2, varscan2
- ADGRL4 | c.1824T>C p.S608= | Silent (SNP) | VAF 20/46 reads (43%) | catalogued as rs778951972, COSV100876580; called by muse, mutect2, varscan2
- AGTPBP1 | c.1728T>C p.T576= (on ENST00000357081 / NM_001330701.2; = p.T536= on NM_015239.2) | Silent (SNP) | VAF 54/127 reads (43%) | catalogued as COSV100430310; called by muse, mutect2, varscan2
- AHDC1 | c.1536C>T p.R512= | Silent (SNP) | VAF 25/57 reads (44%) | catalogued as rs370692975; ClinVar: likely benign; called by muse, mutect2, varscan2
- ALAD | c.522C>T p.R174= | Silent (SNP) | VAF 45/110 reads (41%) | catalogued as rs765852338, COSV52958708; called by muse, mutect2, varscan2
- ANXA11 | c.543C>T p.P181= | Silent (SNP) | VAF 25/58 reads (43%) | catalogued as rs1246222259, COSV55418551, COSV99627262; called by muse, mutect2, varscan2
- AR | c.1086C>A p.R362= | Silent (SNP) | VAF 10/35 reads (29%) | catalogued as COSV101019622, COSV65955089; called by muse, mutect2, varscan2
- ARAP2 | c.627C>T p.L209= | Silent (SNP) | VAF 25/49 reads (51%) | catalogued as COSV100395305; called by muse, mutect2, varscan2
- BPTF | c.7782A>G p.K2594= | Silent (SNP) | VAF 23/65 reads (35%) | catalogued as COSV100076119; called by muse, mutect2, varscan2
- C10orf71 | c.2064T>C p.L688= | Silent (SNP) | VAF 14/32 reads (44%) | catalogued as COSV100110693; called by muse, mutect2, varscan2
- CALCOCO2 | c.654G>A p.K218= | Silent (SNP) | VAF 10/33 reads (30%) | catalogued as COSV99363960; called by muse, mutect2, varscan2
- CAPRIN1 | c.990A>G p.Q330= | Silent (SNP) | VAF 3/22 reads (14%) | catalogued as COSV100404324; called by muse, mutect2
- CCDC60 | c.499C>T p.L167= | Silent (SNP) | VAF 36/79 reads (46%) | catalogued as COSV100554968, COSV100555760; called by muse, mutect2, varscan2
- CCDC88B | c.196C>T p.L66= | Silent (SNP) | VAF 10/23 reads (43%) | catalogued as COSV100105980; called by muse, mutect2, varscan2
- CCT8 | c.243T>C p.P81= | Silent (SNP) | VAF 31/64 reads (48%) | catalogued as COSV99726183; called by muse, mutect2, varscan2
- CDCA4 | c.199C>A p.R67= | Silent (SNP) | VAF 7/29 reads (24%) | catalogued as COSV100288282, COSV60315089; called by muse, mutect2, varscan2
- CFAP74 | c.1755G>A p.K585= | Silent (SNP) | VAF 14/41 reads (34%) | called by muse, mutect2, varscan2
- CFTR | c.3624C>G p.G1208= | Silent (SNP) | VAF 16/36 reads (44%) | catalogued as COSV99140098; called by muse, mutect2, varscan2
- CGNL1 | c.402C>T p.D134= | Silent (SNP) | VAF 22/45 reads (49%) | catalogued as rs367656987, COSV99849237; called by muse, mutect2, varscan2
- CHD2 | c.642T>C p.D214= | Silent (SNP) | VAF 47/103 reads (46%) | catalogued as COSV100560920; called by muse, mutect2, varscan2
- COL11A2 | c.1854T>G p.P618= (on ENST00000341947 / NM_080680.3; = p.P511= on NM_080679.2) | Silent (SNP) | VAF 28/71 reads (39%) | catalogued as COSV100554277, COSV100554582; called by muse, mutect2, varscan2
- CSMD1 | c.5160C>T p.S1720= (on ENST00000520002; = p.S1719= on NM_033225.6) | Silent (SNP) | VAF 38/51 reads (75%) | catalogued as rs983857657, COSV100151822; called by muse, mutect2, varscan2
- CUL3 | c.1122T>C p.F374= | Silent (SNP) | VAF 22/54 reads (41%) | catalogued as COSV100024811; called by muse, mutect2, varscan2
- CYP2C18 | c.792T>C p.I264= | Silent (SNP) | VAF 20/50 reads (40%) | catalogued as COSV99609030; called by muse, mutect2, varscan2
- DIRAS3 | c.285C>T p.G95= | Silent (SNP) | VAF 39/86 reads (45%) | catalogued as rs763794708, COSV63970697, COSV63971085; called by muse, mutect2, varscan2
- DLG2 | c.2046G>A p.P682= | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as rs370359922; called by muse, varscan2
- DMXL1 | c.2526T>C p.L842= | Silent (SNP) | VAF 28/63 reads (44%) | catalogued as COSV100225061; called by muse, mutect2, varscan2
- DNAH8 | c.12507A>G p.S4169= | Silent (SNP) | VAF 30/76 reads (39%) | catalogued as COSV100547296; called by muse, mutect2, varscan2
- DTL | c.162A>G p.G54= | Silent (SNP) | VAF 35/65 reads (54%) | catalogued as COSV100877290; called by muse, mutect2, varscan2
- DUS4L-BCAP29 | c.426A>G p.K142= | Silent (SNP) | VAF 27/65 reads (42%) | catalogued as COSV99143772; called by muse, mutect2, varscan2
- EGF | c.3117C>T p.C1039= | Silent (SNP) | VAF 44/102 reads (43%) | catalogued as rs1560763532, COSV99491397; called by muse, mutect2, varscan2
- EHBP1L1 | c.3435G>A p.E1145= | Silent (SNP) | VAF 5/14 reads (36%) | catalogued as rs1336523396, COSV100500044; called by muse, mutect2
- EXD3 | c.2550C>T p.T850= | Silent (SNP) | VAF 15/40 reads (38%) | catalogued as rs1354782143, COSV100573995; called by muse, mutect2, varscan2
- EXOG | c.831A>G p.G277= | Silent (SNP) | VAF 17/54 reads (31%) | catalogued as COSV99815522; called by muse, mutect2, varscan2
- FBN1 | c.3735T>C p.N1245= | Silent (SNP) | VAF 26/61 reads (43%) | catalogued as COSV100356493; called by muse, mutect2
- FBXL3 | c.1116A>G p.S372= | Silent (SNP) | VAF 12/38 reads (32%) | catalogued as COSV100842333; called by muse, varscan2
- GAB1 | c.1710A>G p.P570= | Silent (SNP) | VAF 17/38 reads (45%) | catalogued as COSV99528867; called by muse, mutect2, varscan2
- HDC | c.1596T>G p.G532= | Silent (SNP) | VAF 6/78 reads (8%) | catalogued as COSV99984346; called by muse, mutect2
- HSP90AB1 | c.1803T>C p.N601= | Silent (SNP) | VAF 18/58 reads (31%) | catalogued as rs781563737, COSV100807223; called by muse, mutect2, varscan2
- ICE2 | c.483G>A p.A161= | Silent (SNP) | VAF 26/53 reads (49%) | catalogued as rs1046505376, COSV99831874; called by muse, mutect2, varscan2
- IL1RAPL2 | c.1872G>A p.E624= | Silent (SNP) | VAF 19/54 reads (35%) | catalogued as COSV100782095; called by muse, mutect2, varscan2
- ITGA9 | c.2193T>C p.S731= | Silent (SNP) | VAF 17/30 reads (57%) | catalogued as COSV99294039; called by muse, mutect2, varscan2
- KCTD20 | c.672T>C p.H224= | Silent (SNP) | VAF 6/44 reads (14%) | catalogued as rs767079421, COSV99536279; called by muse, mutect2, varscan2
- KEAP1 | c.1581T>G p.G527= | Silent (SNP) | VAF 35/72 reads (49%) | catalogued as COSV99408322; called by muse, mutect2, varscan2
- KIF6 | c.1854A>G p.V618= | Silent (SNP) | VAF 44/89 reads (49%) | catalogued as COSV54678170, COSV99760886; called by muse, mutect2, varscan2
- KRTAP5-6 | c.24A>G p.G8= | Silent (SNP) | VAF 118/244 reads (48%) | catalogued as COSV101191788; called by muse, mutect2, varscan2
- LATS2 | c.3108A>G p.A1036= | Silent (SNP) | VAF 41/102 reads (40%) | catalogued as rs368713145; called by muse, mutect2, varscan2
- LRP1B | c.2358T>C p.I786= | Silent (SNP) | VAF 39/80 reads (49%) | catalogued as COSV101261518; called by muse, mutect2, varscan2
- LRRC8D | c.2478C>T p.S826= | Silent (SNP) | VAF 22/60 reads (37%) | catalogued as rs200059113, COSV61581896; called by muse, mutect2, varscan2
- MAB21L1 | c.63A>G p.Q21= | Silent (SNP) | VAF 7/115 reads (6%) | catalogued as COSV100084607; called by muse, mutect2
- MAEA | c.285C>T p.S95= | Silent (SNP) | VAF 38/80 reads (48%) | catalogued as rs574820842, COSV53265736; called by muse, mutect2, varscan2
- MAPK10 | c.864A>G p.K288= (on ENST00000359221 / NM_001351625.2; = p.K326= on NM_002753.5) | Silent (SNP) | VAF 49/111 reads (44%) | catalogued as COSV100175509; called by muse, mutect2, varscan2
- MAST2 | c.4200A>G p.P1400= | Silent (SNP) | VAF 5/29 reads (17%) | catalogued as COSV100788820; called by muse, mutect2, varscan2
- MEGF10 | c.585C>T p.C195= | Silent (SNP) | VAF 34/82 reads (41%) | catalogued as COSV99175744; called by muse, mutect2, varscan2
- MFSD6 | c.675T>C p.T225= | Silent (SNP) | VAF 15/33 reads (45%) | catalogued as COSV99855441; called by muse, mutect2, varscan2
- MPP5 | c.738T>C p.I246= | Silent (SNP) | VAF 21/41 reads (51%) | catalogued as COSV99907458; called by muse, mutect2, varscan2
- MROH5 | c.1146A>G p.A382= | Silent (SNP) | VAF 84/120 reads (70%) | catalogued as COSV101436157; called by muse, mutect2
- MTSS2 | c.606C>T p.T202= | Silent (SNP) | VAF 21/46 reads (46%) | catalogued as COSV100116716; called by muse, mutect2, varscan2
- MUC2 | c.1878T>C p.P626= | Silent (SNP) | VAF 11/109 reads (10%) | catalogued as rs764896646; called by muse, mutect2
- MYH10 | c.444T>C p.H148= | Silent (SNP) | VAF 24/61 reads (39%) | catalogued as COSV99346452; called by muse, mutect2, varscan2
- MYH3 | c.4743T>C p.D1581= | Silent (SNP) | VAF 22/73 reads (30%) | catalogued as COSV99878975; called by muse, mutect2, varscan2
- MYMK | c.297C>T p.F99= | Silent (SNP) | VAF 29/66 reads (44%) | catalogued as rs746799157, COSV60600366, COSV60600955; called by muse, mutect2, varscan2
- NAALADL2 | c.438A>G p.V146= | Silent (SNP) | VAF 14/26 reads (54%) | catalogued as COSV101435796; called by muse, mutect2, varscan2
- NEB | c.9390G>A p.R3130= | Silent (SNP) | VAF 62/132 reads (47%) | catalogued as COSV99428368; called by muse, mutect2, varscan2
- NEB | c.3810T>C p.H1270= | Silent (SNP) | VAF 36/77 reads (47%) | catalogued as COSV99428370; called by muse, mutect2, varscan2
- NEGR1 | c.777A>G p.K259= | Silent (SNP) | VAF 20/39 reads (51%) | catalogued as COSV100166381; called by muse, mutect2, varscan2
- NEXN | c.612C>T p.Y204= | Silent (SNP) | VAF 14/46 reads (30%) | catalogued as rs755062153, COSV99630686; called by muse, varscan2
- NFKB1 | c.2295G>A p.E765= (on ENST00000394820 / NM_001382627.1; = p.E766= on NM_003998.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 31/74 reads (42%) | catalogued as COSV99897930; called by muse, mutect2, varscan2
- NMRAL1 | c.384G>A p.A128= | Silent (SNP) | VAF 15/29 reads (52%) | catalogued as rs750923102, COSV52060259; called by muse, mutect2, varscan2
- NSF | c.1074T>C p.I358= | Silent (SNP) | VAF 30/111 reads (27%) | catalogued as COSV99834059; called by muse, mutect2, varscan2
- NTN5 | c.1056G>A p.S352= | Silent (SNP) | VAF 33/95 reads (35%) | catalogued as rs760107980, COSV54308344; called by muse, mutect2, varscan2
- NXPE4 | c.1575A>G p.V525= (on ENST00000375478 / NM_001077639.2; = p.V241= on NM_017678.3) | Silent (SNP) | VAF 29/55 reads (53%) | catalogued as COSV100970569; called by muse, mutect2, varscan2
- OGT | c.732T>G p.A244= | Silent (SNP) | VAF 16/28 reads (57%) | catalogued as COSV101035649; called by muse, varscan2
- OTOF | c.2892G>A p.A964= (on ENST00000272371 / NM_194248.3; = p.A217= on NM_004802.4) | Silent (SNP) | VAF 67/163 reads (41%) | catalogued as rs756565923, COSV99719096; called by muse, mutect2, varscan2
- P2RY10 | c.150G>A p.L50= | Silent (SNP) | VAF 78/158 reads (49%) | catalogued as COSV99409428; called by muse, mutect2, varscan2
- PAX5 | c.1125C>A p.A375= | Silent (SNP) | VAF 20/53 reads (38%) | catalogued as rs371549995, COSV100814651; called by muse, mutect2, varscan2
- PCDHA3 | c.147G>A p.A49= | Silent (SNP) | VAF 67/150 reads (45%) | catalogued as COSV100973785, COSV65366629; called by muse, mutect2, varscan2
- PCDHA4 | c.1902G>A p.T634= | Silent (SNP) | VAF 80/178 reads (45%) | catalogued as COSV100793181, COSV100793358; called by muse, mutect2, varscan2
- PCDHGA12 | c.2757C>T p.G919= | Silent (SNP) | VAF 18/47 reads (38%) | catalogued as COSV99342503; called by muse, mutect2, varscan2
- PDE3B | c.1185G>A p.R395= | Silent (SNP) | VAF 23/65 reads (35%) | catalogued as COSV99963351; called by muse, mutect2, varscan2
- PDZD4 | c.1257G>T p.A419= | Silent (SNP) | VAF 47/108 reads (44%) | catalogued as rs782730869, COSV99381687; called by muse, mutect2, varscan2
- PRAG1 | c.2145T>G p.P715= | Silent (SNP) | VAF 39/155 reads (25%) | catalogued as rs371525711; called by muse, mutect2, varscan2
- PTBP1 | c.957A>G p.A319= (on ENST00000349038 / NM_031991.4; = p.A345= on NM_002819.5) | Silent (SNP) | VAF 18/60 reads (30%) | catalogued as rs1178129956, COSV100609154; called by muse, mutect2, varscan2
- PTH2R | c.1251T>C p.N417= | Silent (SNP) | VAF 42/90 reads (47%) | catalogued as rs1306236469, COSV99782940; called by muse, mutect2, varscan2
- QKI | c.780C>T p.T260= | Silent (SNP) | VAF 36/80 reads (45%) | catalogued as rs750076096, COSV51692806; called by muse, mutect2, varscan2
- RHBDF1 | c.1344C>T p.Y448= | Silent (SNP) | VAF 9/22 reads (41%) | catalogued as COSV51957541; called by muse, mutect2
- RIPK1 | c.399C>T p.G133= | Silent (SNP) | VAF 38/105 reads (36%) | catalogued as rs781683197, COSV99454957; called by muse, mutect2, varscan2
- ROM1 | c.1002T>C p.P334= | Silent (SNP) | VAF 17/53 reads (32%) | catalogued as COSV99606128; called by muse, mutect2, varscan2
- RPAP1 | c.751C>T p.L251= | Silent (SNP) | VAF 35/63 reads (56%) | catalogued as COSV100427372; called by muse, mutect2, varscan2
- SEL1L | c.2013A>G p.G671= | Silent (SNP) | VAF 30/83 reads (36%) | catalogued as COSV100378135; called by muse, mutect2, varscan2
- SEMA4D | c.63G>A p.A21= | Silent (SNP) | VAF 12/32 reads (38%) | catalogued as rs780457676, COSV100358297; called by muse, mutect2, varscan2
- SESTD1 | c.327G>A p.T109= | Silent (SNP) | VAF 35/71 reads (49%) | catalogued as rs765983135, COSV70568218; called by muse, mutect2, varscan2
- SLC10A3 | c.252C>T p.G84= | Silent (SNP) | VAF 52/146 reads (36%) | catalogued as rs1218866365, COSV99682249; called by muse, mutect2, varscan2
- SLC25A37 | c.792T>A p.T264= | Silent (SNP) | VAF 43/144 reads (30%) | catalogued as COSV99264230; called by muse, mutect2, varscan2
- SLC7A11 | c.492G>T p.A164= | Silent (SNP) | VAF 32/89 reads (36%) | catalogued as rs750795097, COSV99763518; called by muse, mutect2, varscan2
- SLC9B2 | c.1519C>T p.L507= | Silent (SNP) | VAF 38/105 reads (36%) | catalogued as COSV100294399; called by muse, mutect2, varscan2
- SMC1B | c.3189C>T p.Y1063= | Silent (SNP) | VAF 104/183 reads (57%) | catalogued as rs62231141, COSV100663543; called by muse, mutect2, varscan2
- SMU1 | c.1056T>C p.V352= | Silent (SNP) | VAF 19/47 reads (40%) | catalogued as COSV101238595; called by muse, mutect2, varscan2
- SREK1 | c.765G>A p.S255= | Silent (SNP) | VAF 19/34 reads (56%) | catalogued as rs750079764, COSV52332712; called by muse, varscan2
- STAG2 | c.78T>C p.D26= | Silent (SNP) | VAF 61/132 reads (46%) | catalogued as COSV54364940, COSV99495525; called by muse, mutect2, varscan2
- THSD7B | c.534G>A p.R178= | Silent (SNP) | VAF 29/86 reads (34%) | catalogued as COSV55678825; called by muse, mutect2, varscan2
- TKTL2 | c.930A>G p.P310= | Silent (SNP) | VAF 7/19 reads (37%) | catalogued as COSV99761783; called by mutect2, varscan2
- TM9SF2 | c.1494T>C p.I498= | Silent (SNP) | VAF 43/97 reads (44%) | catalogued as COSV100899778; called by muse, mutect2, varscan2
- TMEM184B | c.108G>A p.E36= | Silent (SNP) | VAF 30/63 reads (48%) | catalogued as rs1381216265, COSV100726067; called by muse, mutect2, varscan2
- TMEM207 | c.141T>C p.P47= | Silent (SNP) | VAF 24/59 reads (41%) | catalogued as COSV100719095; called by muse, mutect2, varscan2
- TMEM41A | c.399C>A p.S133= | Silent (SNP) | VAF 22/42 reads (52%) | catalogued as rs765810528, COSV99956724; called by muse, mutect2, varscan2
- TNS2 | c.2283C>T p.G761= (on ENST00000314250 / NM_170754.4; = p.G771= on NM_015319.2) | Silent (SNP) | VAF 31/70 reads (44%) | catalogued as rs773012011, COSV100036919; called by muse, mutect2, varscan2
- TPK1 | c.306T>C p.T102= | Silent (SNP) | VAF 21/45 reads (47%) | catalogued as rs754758107, COSV100766103; called by muse, mutect2, varscan2
- TRIP12 | c.2058T>C p.A686= | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as COSV99390994; called by muse, mutect2, varscan2
- TRMT12 | c.1143A>G p.G381= | Silent (SNP) | VAF 50/80 reads (63%) | catalogued as rs150607772; called by muse, mutect2, varscan2
- TSPOAP1 | c.2439G>A p.P813= | Silent (SNP) | VAF 27/52 reads (52%) | catalogued as rs375728263; called by muse, mutect2
- TTC8 | c.420T>C p.P140= (on ENST00000338104 / NM_001288781.1; = p.P150= on NM_144596.4) | Silent (SNP) | VAF 22/43 reads (51%) | catalogued as rs1476756591, COSV100581675; called by muse, mutect2, varscan2
- TXNRD2 | c.312A>G p.G104= | Silent (SNP) | VAF 4/33 reads (12%) | catalogued as COSV100539175; called by mutect2, varscan2
- VIRMA | c.4395A>G p.K1465= | Silent (SNP) | VAF 70/100 reads (70%) | catalogued as COSV99889574; called by muse, mutect2, varscan2
- VSIG1 | c.945C>A p.I315= | Silent (SNP) | VAF 24/55 reads (44%) | catalogued as COSV99480488; called by muse, mutect2, varscan2
- WDR93 | c.1377A>G p.Q459= | Silent (SNP) | VAF 4/78 reads (5%) | catalogued as COSV99175852; called by muse, mutect2
- WNK2 | c.1602C>T p.D534= | Silent (SNP) | VAF 48/85 reads (56%) | catalogued as COSV52957069; called by muse, mutect2, varscan2
- WNT3 | c.886A>C p.R296= | Silent (SNP) | VAF 29/79 reads (37%) | catalogued as COSV99843443; called by muse, mutect2, varscan2
- WWP2 | c.688T>C p.L230= | Silent (SNP) | VAF 39/107 reads (36%) | catalogued as COSV100598807; called by muse, mutect2, varscan2
- XAB2 | c.234T>C p.R78= | Silent (SNP) | VAF 8/93 reads (9%) | catalogued as COSV100222120; called by muse, mutect2
- XIRP2 | c.2391A>G p.T797= (on ENST00000628543; = p.T972= on NM_152381.6) | Silent (SNP) | VAF 18/36 reads (50%) | catalogued as COSV99747921; called by muse, mutect2, varscan2
- XRCC2 | c.387A>G p.T129= | Silent (SNP) | VAF 14/35 reads (40%) | catalogued as COSV100831703; called by muse, mutect2, varscan2
- YY1AP1 | c.918T>C p.A306= (on ENST00000295566 / NM_139118.2; = p.A229= on NM_018253.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 39/109 reads (36%) | catalogued as COSV99804787; called by muse, mutect2, varscan2
- ZDBF2 | c.168A>C p.P56= | Silent (SNP) | VAF 19/59 reads (32%) | catalogued as COSV100985592; called by muse, mutect2, varscan2
- ZNF114 | c.1200G>A p.S400= | Silent (SNP) | VAF 18/36 reads (50%) | catalogued as rs926698131, COSV59944319; called by muse, mutect2, varscan2
- ZNF462 | c.2805G>A p.P935= | Silent (SNP) | VAF 34/73 reads (47%) | catalogued as rs375810195; called by muse, mutect2, varscan2
- ZNF618 | c.2466C>T p.H822= (on ENST00000374126 / NM_001318042.2; = p.H729= on NM_133374.2) | Silent (SNP) | VAF 21/53 reads (40%) | catalogued as rs766051581, COSV99928961; called by muse, mutect2
- ZNF644 | c.3753A>G p.L1251= (on ENST00000337393 / NM_201269.3; = p.L29= on NM_016620.3) | Silent (SNP) | VAF 6/81 reads (7%) | catalogued as rs1352636554, COSV61345725; called by muse, mutect2
- ZZEF1 | c.1521A>G p.S507= | Silent (SNP) | VAF 29/85 reads (34%) | catalogued as COSV101068116; called by muse, mutect2, varscan2
- ADGRL2 | c.3625+285C>A | Intron (SNP) | VAF 17/49 reads (35%) | catalogued as COSV99586565, COSV99591735; called by muse, mutect2, varscan2
- ATP6V0E2 | c.*221C>T | 3'UTR (SNP) | VAF 32/85 reads (38%) | catalogued as rs373028141; called by muse, mutect2, varscan2
- BRSK2 | c.1939+277dup | Intron (INS) | VAF 40/83 reads (48%) | catalogued as rs751872197; called by mutect2, varscan2
- CLN5 | c.*320A>G | 3'UTR (SNP) | VAF 33/58 reads (57%) | catalogued as COSV62919455; called by muse, mutect2, varscan2
- DIPK1B | chr9:136726818 T>G | 3'Flank (SNP) | VAF 15/40 reads (38%) | called by muse, mutect2, varscan2
- EHMT1 | chr9:137838461 T>C | 3'Flank (SNP) | VAF 21/60 reads (35%) | catalogued as rs779467872; called by muse, mutect2, varscan2
- LPAL2 | n.81G>C | RNA (SNP) | VAF 104/230 reads (45%) | called by muse, mutect2, varscan2
- MIR124-2 | n.70G>A | RNA (SNP) | VAF 90/135 reads (67%) | called by muse, mutect2, varscan2
- MIRLET7A3 | n.7G>T | RNA (SNP) | VAF 27/55 reads (49%) | called by muse, mutect2, varscan2
- RNU7-174P | chr8:80559062 ins T | 5'Flank (INS) | VAF 25/129 reads (19%) | called by mutect2, pindel, varscan2
- SMARCE1 | c.1027+434dup | Intron (INS) | VAF 31/59 reads (53%) | called by mutect2, varscan2
